Somatic mutation profile of tumor specimen TCGA-A5-A0VP-01A (aliquot TCGA-A5-A0VP-01A-21D-A10B-09) from TCGA case TCGA-A5-A0VP, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 74.8 years (27,335 days).
Specimen TCGA-A5-A0VP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 84783f3c-03c3-4492-9d7b-6b968a48ad9a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A5-A0VP-10A (Blood Derived Normal), aliquot TCGA-A5-A0VP-10A-01D-A10B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/22132a71-61b5-4bfd-985b-aa8e3f47e65e

The open-access MAF lists 1,768 somatic variants for this specimen: 1,286 protein-altering or splice-affecting, 459 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,126, Silent 459, Nonsense Mutation 77, Splice Site 25, Frame Shift Del 22, Splice Region 16, Frame Shift Ins 15, Intron 9, RNA 4, 5'Flank 4, 3'UTR 4, Translation Start Site 2.

Variants (750 of 1,768; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL7A1 | c.6005G>A p.R2002H | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs768326843, COSV60395911; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DNAAF1 | c.1906C>T p.R636* | Nonsense Mutation (SNP) | VAF 15/41 reads (37%) | catalogued as rs748869874, COSV58986814; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EBF2 | c.1331G>T p.G444V | Missense Mutation (SNP) | VAF 82/250 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as COSV68776268, COSV68778111; called by muse, mutect2, varscan2
- ERBB3 | c.1423C>T p.R475W | Missense Mutation (SNP) | VAF 36/95 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs1035001455, COSV57246372; called by muse, mutect2, varscan2
- FBXW7 | c.40C>T p.R14* | Nonsense Mutation (SNP) | VAF 58/131 reads (44%) | hotspot (GDC flag); catalogued as rs1362274408, COSV55920408; called by muse, mutect2, varscan2
- KMT2B | c.5113C>T p.R1705* | Nonsense Mutation (SNP) | VAF 81/199 reads (41%) | catalogued as rs1555731976, COSV55862100; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 58/612 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2
- LZTR1 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as rs797045165, CM154919, COSV53145634, COSV53148388; ClinVar: pathogenic; called by muse, varscan2
- MAPK1 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 12/130 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519911, COSV53184855, COSV99308005; ClinVar: likely pathogenic; called by muse, mutect2
- MYH7 | c.1816G>A p.V606M | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs121913627, CM1413733, CM920492, COSV62519806; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PAH | c.472C>T p.R158W | Missense Mutation (SNP) | VAF 43/88 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs75166491, CM930539; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PCCB | c.331C>T p.R111* | Nonsense Mutation (SNP) | VAF 191/436 reads (44%) | catalogued as rs753981900, CM119112, COSV52445460; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 53/131 reads (40%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1625A>T p.E542V | Missense Mutation (SNP) | VAF 99/196 reads (51%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1057519927, COSV55876800, COSV55881194, COSV55893680; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- POGLUT1 | c.652C>T p.R218* | Nonsense Mutation (SNP) | VAF 61/155 reads (39%) | catalogued as rs587777294, CM140062, COSV55156908; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 138/333 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs121913294, CM074465, CM102472, COSV100911374, COSV64288961, COSV64302184; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 89/174 reads (51%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- RB1 | c.1399C>T p.R467* | Nonsense Mutation (SNP) | VAF 13/24 reads (54%) | hotspot (GDC flag); catalogued as rs398123331, CM951106, COSV57296693; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SIN3A | c.2689C>T p.R897* | Nonsense Mutation (SNP) | VAF 138/299 reads (46%) | catalogued as rs1064796919, COSV64583152; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMC1A | c.2368C>T p.R790W | Missense Mutation (SNP) | VAF 171/427 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587784412, CM148620, COSV59129080; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SUFU | c.1022+1G>A p.X341_splice | Splice Site (SNP) | VAF 13/36 reads (36%) | catalogued as rs587776578, CS093600, COSV64013745; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TUBB4A | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.892); catalogued as rs886041021, CM148655, COSV51152978; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AADAC | c.349G>A p.V117M | Missense Mutation (SNP) | VAF 81/209 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs368531215; called by muse, mutect2, varscan2
- ABCA7 | c.1289C>T p.A430V | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as rs1456247540, COSV54030579; called by muse, mutect2, varscan2
- ABCB1 | c.1399C>T p.R467W | Missense Mutation (SNP) | VAF 77/164 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1387356833, COSV55945226, COSV55959906; called by muse, mutect2, varscan2
- ABCB4 | c.1447T>C p.S483P | Missense Mutation (SNP) | VAF 56/235 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.431); catalogued as COSV55935898; called by muse, mutect2, varscan2
- ABCB9 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.582); catalogued as rs1165336149, COSV54892043; called by muse, mutect2, varscan2
- ABCC6 | c.3604G>A p.V1202M | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); catalogued as rs752683023, COSV52741785, COSV99228613; called by muse, mutect2, varscan2
- ABCC8 | c.766G>A p.A256T | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.266); catalogued as rs1329684895, COSV56851349; called by muse, mutect2, varscan2
- ABCG8 | c.1789C>T p.R597W | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs776778929, COSV55393709; called by muse, mutect2, varscan2
- ABHD17B | c.137G>A p.W46* | Nonsense Mutation (SNP) | VAF 72/109 reads (66%) | catalogued as COSV61008030; called by muse, mutect2, varscan2
- ABI3BP | c.1435A>G p.T479A | Missense Mutation (SNP) | VAF 98/789 reads (12%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.482); catalogued as COSV52538013; called by muse, mutect2, varscan2
- ABRAXAS2 | c.1037G>A p.S346N | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as rs761847350, COSV100044831; called by muse, mutect2, varscan2
- ABTB1 | c.1301C>T p.T434M (on ENST00000232744 / NM_172027.3; = p.T292M on NM_032548.3) | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.496); catalogued as rs766497757, COSV51742967; called by muse, mutect2
- ABTB2 | c.1946A>G p.E649G | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV54389163; called by muse, mutect2, varscan2
- AC004922.1 | c.673G>A p.D225N | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.814); catalogued as rs767022179, COSV53557048; called by muse, mutect2, varscan2
- AC006059.2 | c.1849C>T p.R617C | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs984663349, COSV59607180; called by muse, mutect2, varscan2
- AC109583.1 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as rs768769548, COSV59350985; called by muse, mutect2, varscan2
- ACBD3 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 196/540 reads (36%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.885); catalogued as rs767804126, COSV64730401, COSV64730977; called by muse, mutect2, varscan2
- ACO2 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs760882521, COSV53443033; called by muse, mutect2, varscan2
- ACP3 | c.1015C>T p.P339S | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV100313130; called by muse, mutect2
- ACSM2B | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.152); catalogued as rs143779927, COSV61657232; called by muse, mutect2, varscan2
- ACTB | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.978); catalogued as COSV59318818; called by muse, mutect2, varscan2
- ADAM17 | c.2357_2359del p.S786del | In Frame Del (DEL) | VAF 68/172 reads (40%) | catalogued as rs1553355613; called by pindel, varscan2
- ADAMTS19 | c.3143C>T p.A1048V | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as rs369866224; called by muse, mutect2, varscan2
- ADAMTS3 | c.2618G>A p.R873H | Missense Mutation (SNP) | VAF 14/246 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1371868606, COSV99710273; called by muse, mutect2
- ADAMTS9 | c.5183G>T p.R1728L | Missense Mutation (SNP) | VAF 139/341 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.061); catalogued as COSV55782203; called by muse, varscan2
- ADCK2 | c.1373G>C p.G458A | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV50781604; called by muse, mutect2, varscan2
- ADCY6 | c.2002C>T p.R668C | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs546786783, COSV57166935; called by muse, mutect2, varscan2
- ADCY6 | c.20T>C p.L7P | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); catalogued as COSV57168194; called by muse, mutect2, varscan2
- ADCY9 | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53573952; called by muse, mutect2, varscan2
- ADGRF3 | c.3089C>T p.A1030V (on ENST00000311519 / NM_001145168.1; = p.A831V on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as COSV61050620; called by muse, mutect2, varscan2
- ADGRG3 | c.299G>A p.S100N | Missense Mutation (SNP) | VAF 53/116 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV59651261; called by muse, mutect2, varscan2
- ADGRG5 | c.968A>G p.Y323C | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.873); catalogued as rs764808411, COSV61083495; called by muse, mutect2, varscan2
- ADGRL3 | c.1609A>G p.T537A (on ENST00000506720 / NM_001322402.2; = p.T469A on NM_015236.6) | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV72229979; called by muse, mutect2, varscan2
- ADGRV1 | c.11038C>T p.R3680C | Missense Mutation (SNP) | VAF 80/231 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs367738566; called by muse, mutect2, varscan2
- ADIPOR2 | c.91C>T p.R31* | Nonsense Mutation (SNP) | VAF 54/130 reads (42%) | catalogued as rs777795564, COSV63946483; called by muse, mutect2, varscan2
- AFF3 | c.3415G>A p.A1139T | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs756690263, COSV57855940; called by muse, mutect2, varscan2
- AFG3L2 | c.1738G>A p.V580I | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.26); catalogued as rs760219294, COSV52314783; called by muse, mutect2, varscan2
- AGAP3 | c.2269G>A p.V757M (on ENST00000622464; = p.V793M on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1463531575, COSV68244928; called by muse, mutect2, varscan2
- AGGF1 | c.1340G>A p.R447Q | Missense Mutation (SNP) | VAF 104/259 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.033); catalogued as rs762299495, COSV57228257; called by muse, mutect2, varscan2
- AHCTF1 | c.145C>T p.P49S (on ENST00000366508; = p.P23S on NM_015446.5) | Missense Mutation (SNP) | VAF 13/179 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.037); catalogued as COSV100403134; called by muse, mutect2
- AHR | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 213/544 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs746848937, COSV54123805; called by muse, mutect2, varscan2
- AHSG | c.943G>A p.D315N | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.778); catalogued as rs774097503, COSV56607965; called by muse, mutect2, varscan2
- AJAP1 | c.634C>T p.R212W | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs148805869; called by muse, mutect2, varscan2
- AKAP11 | c.3725C>T p.S1242L | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs373903269; called by muse, mutect2, varscan2
- AKAP13 | c.6961C>T p.R2321* (on ENST00000394518 / NM_007200.5; = p.R2325* on NM_006738.6) | Nonsense Mutation (SNP) | VAF 30/98 reads (31%) | catalogued as rs770562501, COSV63459105; called by muse, mutect2, varscan2
- AKAP3 | c.1337C>T p.A446V | Missense Mutation (SNP) | VAF 69/177 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.03); catalogued as rs140732371; called by muse, mutect2, varscan2
- AKAP9 | c.10786-1G>A p.X3596_splice (on ENST00000359028; = p.X3572_splice on NM_005751.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 50/142 reads (35%) | catalogued as COSV62347659; called by muse, mutect2, varscan2
- ALDH1A1 | c.910A>G p.I304V | Missense Mutation (SNP) | VAF 62/106 reads (58%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV52791737; called by muse, mutect2, varscan2
- ALDH3B2 | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.746); catalogued as rs376717625, COSV62428447; called by muse, mutect2, varscan2
- ALPK1 | c.2344C>T p.P782S | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV51585656; called by muse, mutect2, varscan2
- ALPK3 | c.4436G>A p.R1479Q | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759101150, COSV51934079; called by muse, mutect2, varscan2
- ALS2CL | c.2101G>A p.A701T | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs139403177; called by muse, mutect2, varscan2
- ALS2CL | c.1797G>A p.W599* | Nonsense Mutation (SNP) | VAF 9/24 reads (38%) | catalogued as COSV59671694; called by muse, mutect2, varscan2
- AMER1 | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs376626895, COSV57661462; called by muse, mutect2, varscan2
- AMIGO3 | c.1381C>T p.R461W | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs752238885, COSV100246439; called by muse, mutect2, varscan2
- AMIGO3 | c.533A>G p.H178R | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.177); catalogued as rs759116655, COSV57538786; called by muse, mutect2, varscan2
- AMOT | c.2747C>T p.A916V (on ENST00000371959 / NM_001113490.1; = p.A507V on NM_133265.3) | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs1418960734, COSV59063858; called by muse, mutect2, varscan2
- ANAPC15 | c.64C>T p.R22* | Nonsense Mutation (SNP) | VAF 25/78 reads (32%) | catalogued as rs1265144473, COSV56191467, COSV99921493; called by muse, mutect2, varscan2
- ANGEL1 | c.704T>C p.L235P | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.131); catalogued as COSV51873569; called by muse, mutect2, varscan2
- ANGPTL4 | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.57); PolyPhen benign (0.025); catalogued as rs774924877, COSV100035020; called by muse, mutect2
- ANK2 | c.7322C>A p.P2441H | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52163755; called by muse, mutect2, varscan2
- ANK3 | c.10760C>T p.T3587M | Missense Mutation (SNP) | VAF 127/326 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1311916565, COSV55060547; called by muse, mutect2, varscan2
- ANK3 | c.2293A>G p.T765A | Missense Mutation (SNP) | VAF 10/285 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1302272887; called by muse, mutect2
- ANKAR | c.3932G>A p.S1311N | Missense Mutation (SNP) | VAF 22/284 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV51462581; called by muse, mutect2
- ANKFN1 | c.2149A>G p.N717D | Missense Mutation (SNP) | VAF 29/193 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0.13); catalogued as COSV59448659; called by muse, mutect2, varscan2
- ANKLE2 | c.2791C>T p.R931C | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs780612219, COSV63294574; called by muse, varscan2
- ANKMY1 | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 29/237 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs776862271, COSV56035053; called by muse, mutect2, varscan2
- ANKRD1 | c.750+1G>A p.X250_splice | Splice Site (SNP) | VAF 20/42 reads (48%) | catalogued as COSV65467632; called by muse, mutect2, varscan2
- ANKS1A | c.2671C>T p.P891S | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as rs1383168059; called by muse, mutect2
- ANO4 | c.896A>T p.E299V (on ENST00000392977 / NM_001286615.2; = p.E264V on NM_178826.4) | Missense Mutation (SNP) | VAF 24/643 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100152048; called by muse, mutect2
- ANO8 | c.963A>C p.E321D | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.326); catalogued as rs1391585870, COSV50179097; called by muse, mutect2, varscan2
- ANOS1 | c.1517G>A p.R506Q | Missense Mutation (SNP) | VAF 99/284 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.086); catalogued as rs1239045660, COSV52920657; called by muse, mutect2, varscan2
- ANXA4 | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144504684; called by muse, mutect2, varscan2
- AOC2 | c.736A>G p.R246G | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs779113066, COSV53199014, COSV99513492; called by muse, mutect2
- AP1G2 | c.613C>T p.R205* | Nonsense Mutation (SNP) | VAF 4/38 reads (11%) | catalogued as rs369572108; called by mutect2, varscan2
- AP2M1 | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.88); PolyPhen benign (0.006); catalogued as rs1041547140, COSV53048327; called by muse, mutect2, varscan2
- AP3D1 | c.1636G>A p.A546T | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.19); catalogued as rs370017663; called by muse, mutect2
- AP3D1 | c.760C>T p.R254W | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1016180481, COSV61428879; called by muse, mutect2, varscan2
- APC | c.1742A>C p.K581T | Missense Mutation (SNP) | VAF 22/300 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as CD058121, CM058091, CS092033, COSV57323602, COSV99965484; called by muse, mutect2
- APOL1 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 58/141 reads (41%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs753380461, COSV59869114; called by muse, mutect2, varscan2
- APPL2 | c.540G>C p.Q180H | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.995); catalogued as COSV51590834; called by muse, varscan2
- AQR | c.2291C>T p.A764V | Missense Mutation (SNP) | VAF 38/392 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs780179363, COSV99333261; called by muse, mutect2
- AQR | c.1703G>A p.R568H | Missense Mutation (SNP) | VAF 71/210 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.17); catalogued as rs777010010, COSV50035720; called by muse, mutect2, varscan2
- AREL1 | c.1529G>T p.W510L | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.677); catalogued as COSV62666542; called by muse, mutect2, varscan2
- ARF3 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.326); catalogued as COSV99873012; called by muse, mutect2
- ARHGAP10 | c.1364T>C p.I455T | Missense Mutation (SNP) | VAF 45/258 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as rs1224709433, COSV60600068; called by muse, mutect2, varscan2
- ARHGAP29 | c.1234G>C p.A412P | Missense Mutation (SNP) | VAF 38/811 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as COSV99557674; called by muse, mutect2
- ARHGAP30 | c.2603C>T p.A868V | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs538155601, COSV63516821; called by muse, mutect2, varscan2
- ARHGAP32 | c.1450G>A p.D484N (on ENST00000310343 / NM_001378025.1; = p.D135N on NM_014715.4) | Missense Mutation (SNP) | VAF 75/170 reads (44%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.549); catalogued as rs149594456; called by muse, mutect2, varscan2
- ARHGAP35 | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.733); catalogued as rs759238695, COSV68331722; called by muse, mutect2, varscan2
- ARHGAP35 | c.2161G>T p.G721C | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV68331736; called by muse, mutect2, varscan2
- ARHGAP35 | c.3949G>A p.V1317M | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV68330140, COSV68330679; called by muse, mutect2, varscan2
- ARHGAP4 | c.2218G>A p.A740T | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.97); PolyPhen benign (0.001); catalogued as rs782262781, COSV61685783; called by muse, mutect2, varscan2
- ARHGAP9 | c.917C>T p.A306V | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.244); catalogued as COSV57362737; called by muse, mutect2, varscan2
- ARHGEF1 | c.1640C>T p.P547L | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100528892, COSV61526505; called by muse, mutect2, varscan2
- ARHGEF12 | c.4396G>A p.A1466T | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.1); catalogued as COSV63105024, COSV63108073; called by muse, mutect2, varscan2
- ARHGEF2 | c.788C>T p.T263M (on ENST00000361247 / NM_001162383.2; = p.T235M on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as rs199822429, COSV58108720; called by mutect2, varscan2
- ARHGEF37 | c.581C>A p.P194H | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as COSV61368858; called by muse, mutect2, varscan2
- ARL10 | c.541G>A p.V181I | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.2); catalogued as rs766529336, COSV59990755; called by muse, mutect2, varscan2
- ARNT | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 12/230 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1490240303, COSV100590925, COSV62229602; called by muse, mutect2
- ARNTL | c.1580C>T p.T527M (on ENST00000403290 / NM_001297719.2; = p.T526M on NM_001178.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs753548616, COSV62985659; called by muse, mutect2, varscan2
- ARPP19 | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 30/314 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747291355, COSV99992845; called by muse, mutect2
- ASB11 | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1007517047, COSV60355345; called by muse, mutect2, varscan2
- ASB2 | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs747371828, COSV60112097; called by muse, mutect2, varscan2
- ASH1L | c.8200C>T p.R2734C (on ENST00000368346 / NM_001366177.2; = p.R2729C on NM_018489.3) | Missense Mutation (SNP) | VAF 107/244 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV64206896; called by muse, mutect2, varscan2
- ASH1L | c.4457G>A p.R1486H | Missense Mutation (SNP) | VAF 90/209 reads (43%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.996); catalogued as rs769366641, COSV64206987; called by muse, mutect2, varscan2
- ASH2L | c.1453G>A p.V485I | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs767918385, COSV51699794; called by muse, mutect2, varscan2
- ASPH | c.217G>A p.V73I | Missense Mutation (SNP) | VAF 96/243 reads (40%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.258); catalogued as rs774320459, COSV62859433; called by muse, mutect2, varscan2
- ASPM | c.4898G>A p.R1633H | Missense Mutation (SNP) | VAF 55/127 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs181624297, COSV54130632, COSV54131811; called by muse, mutect2, varscan2
- ATG16L2 | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs761289753, COSV58361878; called by muse, mutect2, varscan2
- ATIC | c.601G>A p.V201I | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs549649169, COSV52692704; called by muse, mutect2, varscan2
- ATP11C | c.2165T>C p.L722S | Missense Mutation (SNP) | VAF 15/340 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV100557436; called by muse, mutect2
- ATP1A2 | c.1541G>A p.R514Q | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.655); catalogued as rs748654627, COSV63403701; ClinVar: uncertain significance; called by mutect2, varscan2
- ATP1A4 | c.2381C>T p.T794M | Missense Mutation (SNP) | VAF 55/148 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs140130981; called by muse, mutect2, varscan2
- ATP2A1 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs1280467800, COSV63921282; called by muse, mutect2, varscan2
- ATP2C2 | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV52296679; called by muse, mutect2, varscan2
- ATP6V0B | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs758360388, COSV52543616; called by muse, mutect2, varscan2
- ATP7A | c.1487G>A p.G496D | Missense Mutation (SNP) | VAF 68/165 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58446941; called by muse, mutect2, varscan2
- ATP8A2 | c.2393C>A p.P798H | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99680160; called by muse, mutect2
- ATP8B1 | c.2841G>A p.M947I | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.829); catalogued as rs1399476858, COSV99376853; called by muse, mutect2
- ATP8B2 | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.065); catalogued as COSV59246369, COSV59246521; called by muse, mutect2, varscan2
- ATP8B3 | c.496C>A p.L166I | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.376); catalogued as COSV59543257; called by muse, mutect2, varscan2
- ATP9A | c.2909C>T p.A970V | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as rs772454252, COSV58767210; called by muse, mutect2, varscan2
- ATR | c.6089C>T p.A2030V | Missense Mutation (SNP) | VAF 73/195 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs755650081, COSV63383698, COSV63384373; called by muse, mutect2, varscan2
- ATR | c.2965C>T p.R989C | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as rs911751877, COSV63384264; called by muse, mutect2
- AUP1 | c.421T>C p.S141P | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as COSV51208093; called by muse, mutect2, varscan2
- AXIN1 | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747093980, COSV51988109, COSV51995541; called by muse, mutect2, varscan2
- BAHCC1 | c.3722C>T p.P1241L | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as rs375132882; called by muse, mutect2, varscan2
- BAIAP3 | c.1757G>A p.R586Q | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as rs777857668, COSV50104044; called by muse, mutect2, varscan2
- BARHL2 | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs1312809958, COSV64980950; called by muse, mutect2, varscan2
- BCL9 | c.527T>C p.V176A | Missense Mutation (SNP) | VAF 19/191 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.428); catalogued as COSV52344849; called by muse, mutect2, varscan2
- BCL9L | c.3343G>A p.D1115N | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1170065671, COSV99418620; called by muse, mutect2
- BCOR | c.4742-2A>G p.X1581_splice (on ENST00000378444 / NM_001123385.2; = p.X1547_splice on NM_017745.6) | Splice Site (SNP) | VAF 7/66 reads (11%) | catalogued as COSV60708428; called by muse, mutect2, varscan2
- BCORL1 | c.4396C>T p.R1466W | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54397243, COSV99499938; called by muse, mutect2, varscan2
- BEND5 | c.839C>T p.S280F | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.205); catalogued as COSV65717483; called by muse, mutect2, varscan2
- BICDL1 | c.1616G>A p.R539Q | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs772169138, COSV57492440, COSV57493475; called by muse, mutect2, varscan2
- BICRAL | c.506C>T p.T169M | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as COSV58405926; called by muse, mutect2, varscan2
- BLM | c.1927C>T p.R643C | Missense Mutation (SNP) | VAF 71/177 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs373090621, COSV61922089; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BMP1 | c.1508G>A p.S503N | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.626); catalogued as COSV60479832; called by muse, mutect2, varscan2
- BMP2K | c.2941C>T p.R981C | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1335782363, COSV55009947; called by muse, mutect2, varscan2
- BRD1 | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as rs555085765, COSV99349287, COSV99349825; called by muse, mutect2, varscan2
- BRF1 | c.1715G>A p.R572Q | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.347); catalogued as rs746602408, COSV59265589; called by mutect2, varscan2
- BRF2 | c.850C>T p.R284* | Nonsense Mutation (SNP) | VAF 12/30 reads (40%) | catalogued as rs766442478, COSV55103992; called by muse, mutect2, varscan2
- BRINP1 | c.1379G>A p.R460H | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.98); catalogued as rs751091448, COSV56301366; called by muse, mutect2, varscan2
- BRINP3 | c.969C>G p.F323L | Missense Mutation (SNP) | VAF 60/144 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.899); catalogued as COSV66525902; called by muse, mutect2, varscan2
- BRIX1 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.637); catalogued as COSV57715265; called by muse, mutect2, varscan2
- BRS3 | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.168); catalogued as rs376207740, COSV65710669; called by muse, mutect2, varscan2
- BSN | c.2318C>T p.S773F | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56519192; called by muse, mutect2, varscan2
- BTBD6 | c.1262C>T p.P421L | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as rs1478738643, COSV59265879; called by muse, mutect2
- BTN3A3 | c.1079G>T p.R360M | Missense Mutation (SNP) | VAF 63/165 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV55072239; called by muse, mutect2, varscan2
- BTNL2 | c.1110G>T p.E370D | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.755); catalogued as COSV66630886; called by muse, mutect2, varscan2
- C10orf71 | c.179C>T p.T60I | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as COSV100109722; called by muse, mutect2
- C14orf93 | c.1127G>A p.R376H | Missense Mutation (SNP) | VAF 59/150 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs778432140, COSV54440944; called by muse, mutect2, varscan2
- C17orf80 | c.922G>T p.G308W | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52146827; called by muse, mutect2, varscan2
- C1orf162 | c.4G>A p.G2R | Missense Mutation (SNP) | VAF 10/141 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100636158; called by muse, mutect2
- C5orf38 | c.205G>A p.V69M | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.596); catalogued as COSV57411505; called by muse, mutect2, varscan2
- C8B | c.850C>T p.R284* | Nonsense Mutation (SNP) | VAF 120/326 reads (37%) | catalogued as rs374155702; called by muse, mutect2
- CA6 | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66262211; called by muse, mutect2, varscan2
- CACNA1A | c.5096A>G p.Y1699C | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100801043; called by muse, mutect2, varscan2
- CACNA1I | c.4288G>A p.V1430M | Missense Mutation (SNP) | VAF 138/341 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60809804; called by muse, mutect2, varscan2
- CACNA1S | c.1172G>A p.G391D | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.145); catalogued as COSV100754671; called by muse, mutect2
- CACNA1S | c.728C>T p.S243L | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.558); catalogued as rs1414181449, COSV100754673; called by muse, mutect2
- CACNA2D2 | c.2152G>A p.D718N (on ENST00000479441 / NM_001174051.3; = p.D711N on NM_006030.4) | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT tolerated (0.89); PolyPhen possibly damaging (0.602); catalogued as COSV56564043; called by muse, mutect2, varscan2
- CACNG3 | c.82G>A p.V28M | Missense Mutation (SNP) | VAF 126/284 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50069403; called by muse, mutect2, varscan2
- CACTIN | c.2066G>A p.R689H | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0.366); catalogued as COSV50268326; called by muse, varscan2
- CADM4 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.257); catalogued as COSV99731370; called by muse, mutect2
- CAMSAP2 | c.2294G>T p.R765M (on ENST00000236925 / NM_001297707.2; = p.R754M on NM_203459.3) | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV52671526; called by muse, mutect2, varscan2
- CAPN7 | c.2233A>G p.T745A | Missense Mutation (SNP) | VAF 36/371 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV99508078; called by muse, mutect2, varscan2
- CASKIN2 | c.833G>A p.R278Q | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764898186, COSV58691114; called by muse, mutect2, varscan2
- CAVIN1 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63811961; called by muse, mutect2, varscan2
- CCAR2 | c.1940C>T p.A647V | Missense Mutation (SNP) | VAF 161/381 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.257); catalogued as COSV52384762; called by muse, mutect2, varscan2
- CCDC127 | c.336G>T p.K112N | Missense Mutation (SNP) | VAF 80/206 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.307); catalogued as COSV57256940; called by muse, mutect2, varscan2
- CCDC47 | c.1328G>A p.R443Q | Missense Mutation (SNP) | VAF 10/282 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs976393994, COSV99853981; called by muse, mutect2
- CCDC91 | c.1312G>A p.V438I | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV60342818; called by muse, mutect2, varscan2
- CCKAR | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs115488558; called by muse, mutect2, varscan2
- CCN4 | c.917A>T p.D306V | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51532381; called by muse, mutect2, varscan2
- CCNF | c.1028G>A p.R343Q | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.7); PolyPhen benign (0.012); catalogued as rs772205153, COSV53540255; called by muse, mutect2, varscan2
- CCR7 | c.1001G>A p.R334H | Missense Mutation (SNP) | VAF 36/61 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1442842565, COSV55849574; called by muse, mutect2, varscan2
- CD101 | c.1733C>T p.T578M | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.211); catalogued as rs201016506, COSV56718337; called by muse, mutect2, varscan2
- CD22 | c.2296C>T p.R766C | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs372211109; called by muse, mutect2, varscan2
- CD247 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs768293096, COSV62978247; called by muse, mutect2, varscan2
- CD5 | c.1078T>C p.C360R | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61718478; called by muse, mutect2, varscan2
- CD5L | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.977); catalogued as rs747471540, COSV63821212; called by muse, mutect2, varscan2
- CD72 | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.545); catalogued as COSV52411260; called by muse, mutect2, varscan2
- CDC16 | c.1657A>G p.K553E | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.219); catalogued as COSV52959767; called by muse, mutect2, varscan2
- CDC6 | c.1085T>C p.V362A | Missense Mutation (SNP) | VAF 60/233 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1230435122, COSV52930636; called by muse, mutect2, varscan2
- CDCA2 | c.2848A>G p.M950V | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57946145; called by muse, mutect2, varscan2
- CDH10 | c.1225A>G p.R409G | Missense Mutation (SNP) | VAF 77/224 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.355); catalogued as rs757220666, COSV52582709; called by muse, mutect2, varscan2
- CDH16 | c.823C>A p.H275N | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.115); catalogued as COSV55336896, COSV55340300; called by muse, mutect2, varscan2
- CDH19 | c.1874T>C p.I625T | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs998783491, COSV50960253; called by muse, mutect2, varscan2
- CDH2 | c.713A>G p.H238R | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV52281737; called by muse, mutect2, varscan2
- CDH7 | c.1282G>T p.D428Y | Missense Mutation (SNP) | VAF 55/113 reads (49%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.973); catalogued as COSV59887076, COSV59890101; called by muse, mutect2, varscan2
- CELA2B | c.469G>A p.V157I | Missense Mutation (SNP) | VAF 62/127 reads (49%) | SIFT tolerated (0.75); PolyPhen benign (0.289); catalogued as COSV65545555; called by muse, mutect2, varscan2
- CEMIP2 | c.1338G>T p.E446D | Missense Mutation (SNP) | VAF 73/130 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV65487490; called by muse, mutect2, varscan2
- CENPT | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.648); catalogued as rs1409836167, COSV54650038; called by muse, mutect2, varscan2
- CEP250 | c.2242G>A p.V748M | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.11); catalogued as rs754323656, COSV61169976; called by muse, mutect2, varscan2
- CEP290 | c.635dup p.N212Kfs*3 | Frame Shift Ins (INS) | VAF 166/469 reads (35%) | catalogued as rs769091629; called by mutect2, varscan2
- CGB2 | c.338G>A p.R113H | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV56819978; called by muse, mutect2, varscan2
- CHD3 | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.446); catalogued as rs778123554, COSV57875694; called by muse, mutect2, varscan2
- CHD3 | c.2242C>T p.R748C | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57875709; called by muse, mutect2, varscan2
- CHD6 | c.6868A>G p.R2290G | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100950574; called by muse, mutect2
- CHD7 | c.3566G>A p.R1189H | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1554599432, CM137512, COSV71111282; ClinVar: uncertain significance; called by muse, mutect2
- CHD8 | c.5222C>T p.P1741L (on ENST00000646647 / NM_001170629.2; = p.P1462L on NM_020920.4) | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.129); catalogued as rs749428842, COSV63036553; called by muse, mutect2, varscan2
- CHMP2A | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV53396338; called by muse, mutect2, varscan2
- CHPF2 | c.2153G>A p.R718Q | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367722805; called by muse, mutect2, varscan2
- CHRD | c.2390C>T p.T797M | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs763703209, COSV52608675; called by muse, varscan2
- CHSY1 | c.1198G>A p.A400T | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.43); PolyPhen benign (0.072); catalogued as rs573681382, COSV54253531; called by muse, mutect2, varscan2
- CIAO1 | c.532C>T p.R178W | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.913); catalogued as rs1173021812, COSV51497988; called by muse, mutect2, varscan2
- CIBAR1 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 80/193 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as rs1240065498, COSV63897440; called by muse, mutect2, varscan2
- CIC | c.1799G>A p.R600H | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.382); catalogued as rs551970875, COSV99359013; called by muse, mutect2
- CIITA | c.2888+1G>A p.X963_splice | Splice Site (SNP) | VAF 21/45 reads (47%) | catalogued as rs372826934, CS930846; ClinVar: conflicting interpretations of pathogenicity / pathogenic; called by muse, mutect2, varscan2
- CIPC | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.69); catalogued as rs201665496, COSV62377023; called by muse, mutect2, varscan2
- CIR1 | c.668A>G p.K223R | Missense Mutation (SNP) | VAF 46/614 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV100564873; called by muse, mutect2
- CLCN6 | c.1876C>T p.R626C | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV56740416; called by muse, mutect2, varscan2
- CLDN1 | c.631G>A p.V211M | Missense Mutation (SNP) | VAF 195/492 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as rs147881276, COSV55044256; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLEC4C | c.235+2T>C p.X79_splice | Splice Site (SNP) | VAF 14/209 reads (7%) | catalogued as COSV100665365; called by muse, mutect2
- CLEC4F | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.614); catalogued as rs781822853, COSV99713540; called by muse, mutect2
- CLINT1 | c.1301T>C p.M434T | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as COSV51624577; called by muse, mutect2, varscan2
- CLIP2 | c.2936C>T p.S979L | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs782033519, COSV56279819; called by muse, mutect2, varscan2
- CLUH | c.2899G>A p.V967M (on ENST00000435359; = p.V1006M on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs1332669209, COSV70928815; called by muse, mutect2, varscan2
- CMYA5 | c.11429G>A p.R3810H | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1230455915, COSV71406249; called by muse, varscan2
- CMYA5 | c.11476C>T p.R3826W | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.857); catalogued as rs755707378, COSV71406250; called by muse, varscan2
- CNDP1 | c.1522T>C p.*508Qext*9 | Nonstop Mutation (SNP) | VAF 119/327 reads (36%) | catalogued as COSV62594003; called by muse, mutect2, varscan2
- CNRIP1 | c.257C>T p.T86M | Missense Mutation (SNP) | VAF 61/143 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as rs377749015; called by muse, mutect2, varscan2
- CNTN4 | c.2989G>A p.A997T | Missense Mutation (SNP) | VAF 79/186 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.508); catalogued as rs770331463, COSV61873890; called by muse, mutect2, varscan2
- CNTNAP1 | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.489); catalogued as COSV52850905; called by muse, mutect2, varscan2
- CNTNAP2 | c.1943C>T p.T648M | Missense Mutation (SNP) | VAF 54/119 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as rs534215627, COSV62148754; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTNAP5 | c.2359C>T p.R787* | Nonsense Mutation (SNP) | VAF 71/174 reads (41%) | catalogued as COSV101443851, COSV70486688; called by muse, mutect2, varscan2
- COL12A1 | c.3091C>T p.R1031C | Missense Mutation (SNP) | VAF 223/516 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.91); catalogued as rs575168916, COSV59396982; called by muse, mutect2, varscan2
- COL14A1 | c.2056G>A p.G686S | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.071); catalogued as rs76456653, COSV52868272; called by muse, mutect2, varscan2
- COL22A1 | c.2723C>T p.A908V | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.042); catalogued as COSV100276479; called by muse, mutect2, varscan2
- COL7A1 | c.8684G>A p.R2895Q | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.942); catalogued as rs147911102; called by muse, mutect2, varscan2
- COL9A3 | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.837); catalogued as rs756660482, COSV59655245; called by muse, mutect2
- COLGALT1 | c.557C>T p.T186M | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1439595039, COSV53109490; called by muse, mutect2, varscan2
- COPA | c.842G>A p.R281Q | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1485520703, COSV54103338; called by muse, mutect2, varscan2
- COQ8B | c.404C>T p.S135L | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.509); catalogued as rs987711849, COSV99699306; called by muse, mutect2
- CPAMD8 | c.571C>T p.R191* (on ENST00000651564; = p.R144* on NM_015692.5) | Nonsense Mutation (SNP) | VAF 22/50 reads (44%) | catalogued as rs764973886, COSV52234979; called by muse, mutect2, varscan2
- CPB2 | c.364C>T p.Q122* | Nonsense Mutation (SNP) | VAF 80/127 reads (63%) | catalogued as rs751480044, COSV51674780; called by muse, mutect2, varscan2
- CPNE2 | c.709G>A p.G237R | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1467832560, COSV51962599; called by muse, mutect2, varscan2
- CPNE2 | c.1264C>T p.R422W | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs751124765, COSV51962612; called by muse, mutect2, varscan2
- CPSF2 | c.1877C>T p.A626V | Missense Mutation (SNP) | VAF 105/283 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.099); catalogued as rs765171535, COSV54098605; called by muse, mutect2, varscan2
- CPXM1 | c.1864C>T p.R622C | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs760210168, COSV66045523; called by muse, mutect2, varscan2
- CPXM2 | c.1258C>A p.P420T | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53862926; called by muse, mutect2, varscan2
- CREM | c.349C>T p.R117* (on ENST00000429130; = p.R68* on NM_001881.3) | Nonsense Mutation (SNP) | VAF 8/147 reads (5%) | catalogued as rs1455658038, COSV100414993; called by muse, mutect2
- CRP | c.283G>A p.V95M | Missense Mutation (SNP) | VAF 87/231 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54813662; called by muse, mutect2, varscan2
- CRYBA2 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.584); catalogued as COSV55388198; called by muse, mutect2, varscan2
- CSMD3 | c.11078C>T p.A3693V (on ENST00000297405 / NM_001363185.1; = p.A3524V on NM_052900.3) | Missense Mutation (SNP) | VAF 156/413 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as rs768386869, COSV52135480; called by muse, mutect2, varscan2
- CSRNP3 | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.995); catalogued as rs369735548, COSV100086138; called by muse, mutect2
- CTIF | c.1084G>A p.V362M | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as rs202183503, COSV56484658; called by muse, mutect2, varscan2
- CTNNA1 | c.1136G>A p.R379H | Missense Mutation (SNP) | VAF 110/252 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs760356703, COSV57070345; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTSG | c.643G>A p.V215I | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.543); catalogued as rs758122544, COSV53535691; called by muse, mutect2, varscan2
- CTXN3 | c.148C>T p.R50W | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1247234077, COSV65218025; called by muse, mutect2, varscan2
- CUL9 | c.7492C>A p.L2498M | Missense Mutation (SNP) | VAF 53/144 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.942); catalogued as COSV52729225; called by muse, mutect2, varscan2
- CWH43 | c.733T>G p.L245V | Missense Mutation (SNP) | VAF 50/526 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.643); catalogued as COSV99892849; called by muse, mutect2
- CXCR2 | c.622C>T p.R208W | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768791823, COSV59280832; called by muse, mutect2, varscan2
- CYLD | c.2179G>A p.V727I | Missense Mutation (SNP) | VAF 111/286 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.043); catalogued as rs762650238, COSV61094909; called by muse, mutect2, varscan2
- CYP1A1 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.947); catalogued as rs367709511, COSV65696821; called by muse, mutect2, varscan2
- CYP1A2 | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758124536, COSV59659850; called by muse, mutect2, varscan2
- CYP2F1 | c.1436A>T p.N479I | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV58527754; called by muse, mutect2, varscan2
- CYP2R1 | c.842T>C p.L281S | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100584849; called by muse, mutect2
- DACT1 | c.2158G>A p.V720M | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.747); catalogued as rs1229565624, COSV100241593; called by muse, mutect2
- DACT1 | c.2431A>G p.K811E | Missense Mutation (SNP) | VAF 51/158 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60021104; called by muse, mutect2, varscan2
- DAG1 | c.2401G>A p.A801T | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as COSV58184654; called by muse, mutect2, varscan2
- DCAF5 | c.2002C>T p.R668C | Missense Mutation (SNP) | VAF 36/224 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs367661585; called by muse, mutect2
- DCBLD2 | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 88/178 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as rs374307805; called by muse, mutect2, varscan2
- DCDC1 | c.3133G>C p.A1045P (on ENST00000597505 / NM_001367979.1; = p.A152P on NM_020869.3) | Missense Mutation (SNP) | VAF 170/395 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.372); catalogued as COSV60306869, COSV60309753; called by muse, mutect2, varscan2
- DCN | c.662C>A p.P221H | Missense Mutation (SNP) | VAF 87/266 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.501); catalogued as COSV50007289; called by muse, mutect2, varscan2
- DCP2 | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs773419110, COSV66617104; called by muse, mutect2, varscan2
- DDI1 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.847); catalogued as COSV56373290; called by muse, mutect2, varscan2
- DDI2 | c.223C>T p.R75* | Nonsense Mutation (SNP) | VAF 65/131 reads (50%) | catalogued as COSV60779907; called by muse, mutect2, varscan2
- DDX47 | c.1207G>A p.V403I | Missense Mutation (SNP) | VAF 58/143 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.059); catalogued as rs763297686, COSV61911477; called by muse, mutect2, varscan2
- DDX54 | c.253G>A p.V85M | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV58372622; called by muse, mutect2, varscan2
- DENND2A | c.1676A>G p.Y559C | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV52052114; called by muse, mutect2, varscan2
- DENND3 | c.649G>A p.V217I | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as rs571831372, COSV52801720; called by muse, mutect2, varscan2
- DENND4A | c.3605G>A p.R1202H | Missense Mutation (SNP) | VAF 7/167 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs912976987, COSV71265469; called by muse, mutect2
- DHX34 | c.1363G>A p.V455I | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.691); catalogued as rs763768330, COSV60895664; called by muse, mutect2, varscan2
- DHX37 | c.1856C>T p.A619V | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58135020; called by muse, mutect2, varscan2
- DIP2A | c.4492G>C p.V1498L | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV59478464; called by muse, mutect2, varscan2
- DLC1 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 52/106 reads (49%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.425); catalogued as rs368389913, COSV99363842; called by muse, mutect2, varscan2
- DLD | c.515A>G p.Q172R | Missense Mutation (SNP) | VAF 71/202 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.05); catalogued as rs1181351839, COSV52738183; called by muse, mutect2, varscan2
- DLG4 | c.832C>A p.L278M (on ENST00000399506 / NM_001321075.3; = p.L321M on NM_001365.4) | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.25); PolyPhen benign (0.065); catalogued as COSV57239042; called by muse, mutect2, varscan2
- DMBT1 | c.2011T>A p.C671S | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.375); catalogued as COSV57545588; called by muse, mutect2, varscan2
- DMBX1 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1424205121, COSV63601784; called by muse, mutect2
- DMWD | c.1075C>T p.R359C | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755365606, COSV52180145; called by muse, mutect2, varscan2
- DNAH1 | c.2526C>T p.S842= | Splice Region (SNP) | VAF 4/13 reads (31%) | catalogued as rs779492998, COSV101324771; called by muse, mutect2
- DNAH17 | c.12656C>T p.A4219V | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); catalogued as COSV99428027; called by muse, mutect2, varscan2
- DNAH17 | c.11492G>A p.R3831H | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756102467, COSV67755507; called by muse, mutect2, varscan2
- DNAH2 | c.9612+1G>A p.X3204_splice | Splice Site (SNP) | VAF 6/36 reads (17%) | catalogued as COSV101209025; called by muse, mutect2
- DNAH3 | c.2428C>T p.R810C | Missense Mutation (SNP) | VAF 93/252 reads (37%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.634); catalogued as rs373910467; called by muse, mutect2, varscan2
- DNAH5 | c.9961C>T p.R3321W | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs763063590, COSV54212472; called by muse, mutect2, varscan2
- DNAH5 | c.6268C>T p.R2090W | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774191944, COSV54217609; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAI4 | c.2036G>T p.G679V | Missense Mutation (SNP) | VAF 91/215 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs78356162, COSV64029702; called by muse, mutect2, varscan2
- DNAJB7 | c.5T>C p.V2A | Missense Mutation (SNP) | VAF 82/204 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.02); catalogued as COSV53421995; called by muse, mutect2, varscan2
- DNAJB8 | c.10T>C p.Y4H | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100048108; called by muse, mutect2
- DOCK3 | c.943C>T p.R315* | Nonsense Mutation (SNP) | VAF 37/101 reads (37%) | catalogued as COSV56524515; called by muse, mutect2, varscan2
- DOP1A | c.1835G>A p.R612Q | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.021); catalogued as rs562390207, COSV52708954, COSV99381549; called by muse, mutect2
- DPEP3 | c.756G>A p.E252= | Splice Region (SNP) | VAF 20/57 reads (35%) | catalogued as rs1415356691, COSV52051472; called by muse, mutect2, varscan2
- DPEP3 | c.241C>T p.R81W | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs1419111203, COSV52051482; called by muse, mutect2, varscan2
- DPP9 | c.59C>T p.P20L (on ENST00000598800; = p.P49L on NM_139159.5) | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs781767492, COSV53589229; called by muse, mutect2, varscan2
- DSP | c.3165C>G p.N1055K | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0.061); catalogued as COSV65793118; called by muse, mutect2, varscan2
- DSP | c.8462C>T p.S2821L | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as rs201826850, COSV60939119; ClinVar: uncertain significance / likely benign; called by muse, mutect2
- DSPP | c.3071G>A p.S1024N | Missense Mutation (SNP) | VAF 22/238 reads (9%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.427); catalogued as COSV99216523; called by mutect2, varscan2
- DSTYK | c.2369G>A p.R790H | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs767549596, COSV65686692; called by muse, mutect2, varscan2
- DTNB | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs773276883, COSV56477704, COSV99977058; called by muse, mutect2, varscan2
- DUS3L | c.942G>A p.T314= | Splice Region (SNP) | VAF 11/26 reads (42%) | catalogued as rs745638565, COSV57832118; called by muse, mutect2, varscan2
- DYNC1H1 | c.3572G>A p.R1191H | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs1003718521, COSV64134426; called by muse, mutect2, varscan2
- DYNC1H1 | c.6421G>A p.V2141I | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.75); PolyPhen benign (0.024); catalogued as rs765613848, COSV64137265, COSV64137462; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYNC2H1 | c.7031G>A p.R2344H | Missense Mutation (SNP) | VAF 56/136 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs775250788, COSV62094712; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYNLL1 | c.70T>C p.C24R | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as COSV54359752; called by muse, mutect2, varscan2
- ECE1 | c.1903G>A p.V635M | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs1316358496, COSV51665239; called by muse, mutect2, varscan2
- EEPD1 | c.879-1G>A p.X293_splice | Splice Site (SNP) | VAF 63/250 reads (25%) | catalogued as COSV54198755; called by muse, mutect2, varscan2
- EFCAB6 | c.1896A>G p.I632M | Missense Mutation (SNP) | VAF 78/548 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.135); catalogued as COSV53064382; called by muse, mutect2, varscan2
- EFHC1 | c.572A>G p.Q191R | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV64136472; called by muse, mutect2, varscan2
- EIF2AK1 | c.1309G>A p.G437R | Missense Mutation (SNP) | VAF 111/339 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52239952; called by muse, mutect2, varscan2
- EIF3D | c.1495A>G p.M499V | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as COSV53400102; called by muse, mutect2, varscan2
- EIF4G2 | c.1504C>T p.Q502* | Nonsense Mutation (SNP) | VAF 134/374 reads (36%) | catalogued as COSV60597236; called by muse, mutect2, varscan2
- ELAPOR2 | c.2939G>T p.C980F (on ENST00000450689 / NM_001142749.3; = p.C813F on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 98/246 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51887346; called by muse, mutect2, varscan2
- ELAVL1 | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); catalogued as COSV60966762; called by muse, varscan2
- ELP4 | c.833A>C p.N278T (on ENST00000350638; = p.N277T on NM_019040.5) | Missense Mutation (SNP) | VAF 61/153 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV63353139; called by muse, mutect2, varscan2
- EML3 | c.2318G>T p.W773L | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV99604026; called by muse, mutect2
- EMSY | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 7/172 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV100595420; called by muse, mutect2
- ENG | c.308G>A p.S103N | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.045); catalogued as COSV61227627; called by muse, mutect2, varscan2
- ENOX2 | c.664G>A p.A222T (on ENST00000338144 / NM_001382520.1; = p.A193T on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/208 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.571); catalogued as COSV100583792; called by muse, mutect2
- ENTPD1 | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 28/289 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV100967370; called by muse, mutect2
- ENTPD6 | c.386C>T p.T129M | Missense Mutation (SNP) | VAF 85/280 reads (30%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.964); catalogued as rs545735578, COSV61751578; called by muse, mutect2, varscan2
- EP400 | c.6563C>T p.T2188M | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs781540945, COSV57773787; called by muse, mutect2, varscan2
- EPB41 | c.1864G>A p.E622K (on ENST00000343067 / NM_001166005.2; = p.E413K on NM_203342.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 88/228 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs995238557, COSV100548137, COSV58047502; called by muse, mutect2, varscan2
- EPHA4 | c.2212T>C p.S738P | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56034520; called by muse, mutect2, varscan2
- EPHA4 | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 167/387 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.196); catalogued as rs184759178, COSV56030187, COSV56034541; called by muse, mutect2, varscan2
- EPHB2 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); catalogued as rs1318420169, COSV65862903; called by muse, mutect2, varscan2
- EPHB3 | c.2245C>A p.L749M | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV57806322; called by muse, mutect2, varscan2
- EPPK1 | c.5806G>A p.A1936T | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371992082; called by muse, mutect2, varscan2
- EPPK1 | c.5432G>A p.R1811Q | Missense Mutation (SNP) | VAF 93/230 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.051); catalogued as rs200136005, COSV73261037; called by muse, mutect2, varscan2
- EPPK1 | c.1889G>A p.R630Q | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as rs372641252; called by muse, mutect2, varscan2
- EPX | c.1448G>A p.R483H | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs575861164, COSV56595607; called by muse, mutect2, varscan2
- ERAP1 | c.305T>C p.I102T | Missense Mutation (SNP) | VAF 66/196 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1449075742, COSV57088356; called by muse, mutect2, varscan2
- ERBB2 | c.3722C>A p.P1241H | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99506776; called by muse, mutect2
- ERC1 | c.17G>A p.R6H | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as rs140435811; called by muse, mutect2, varscan2
- ERGIC3 | c.1111C>T p.R371* | Nonsense Mutation (SNP) | VAF 4/52 reads (8%) | catalogued as rs769257293, COSV99481796; called by mutect2, varscan2
- ERICH6 | c.1813C>T p.R605C | Missense Mutation (SNP) | VAF 17/213 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs370477652; called by muse, mutect2
- ERN2 | c.1727G>A p.R576H | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55620624; called by muse, mutect2, varscan2
- ERVFRD-1 | c.1393C>T p.R465* | Nonsense Mutation (SNP) | VAF 30/72 reads (42%) | catalogued as rs777849179, COSV65369221; called by muse, mutect2, varscan2
- ESPNL | c.1669C>T p.R557W | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.446); catalogued as rs764339336, COSV58035003; called by muse, mutect2, varscan2
- ETV1 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 52/113 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.959); catalogued as rs748346103, COSV54139580, COSV99624951; called by muse, mutect2, varscan2
- EVA1A | c.177C>G p.C59W | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.15); catalogued as COSV52058979; called by muse, mutect2, varscan2
- EVPL | c.4286G>A p.R1429H | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.025); catalogued as rs758336462, COSV56911793; called by muse, mutect2, varscan2
- EXOC3 | c.25G>A p.V9I | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.46); PolyPhen benign (0.041); catalogued as rs772714763, COSV59266902; called by muse, mutect2, varscan2
- EXOSC9 | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 70/194 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as rs776925374, COSV54666218; called by muse, mutect2, varscan2
- EXTL2 | c.388A>G p.R130G | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as COSV100921085; called by muse, mutect2
- EXTL3 | c.1588G>A p.V530M | Missense Mutation (SNP) | VAF 23/32 reads (72%) | SIFT tolerated (0.05); PolyPhen benign (0.165); catalogued as rs138950489; called by muse, mutect2, varscan2
- EYA2 | c.908G>A p.R303H | Missense Mutation (SNP) | VAF 76/188 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.767); catalogued as rs780109158, COSV57942494; called by muse, mutect2, varscan2
- EYA2 | c.1439A>G p.K480R | Missense Mutation (SNP) | VAF 22/236 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100426517; called by muse, mutect2
- FADS2 | c.586C>A p.L196I | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as COSV99608418; called by muse, mutect2
- FAM111B | c.1466G>A p.R489Q | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0.062); catalogued as rs767471589, COSV59112137; called by muse, mutect2, varscan2
- FAM135A | c.4175G>A p.R1392Q (on ENST00000370479 / NM_001351599.1; = p.R1179Q on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 63/154 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760555481, COSV52052276; called by muse, mutect2, varscan2
- FAM135B | c.3974G>T p.R1325M | Missense Mutation (SNP) | VAF 16/310 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99419284; called by muse, mutect2
- FAM193B | c.1274C>T p.A425V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs759146797, COSV61557329, COSV61557872; called by muse, mutect2, varscan2
- FAM222B | c.932C>T p.S311L | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.55); catalogued as rs372959774; called by muse, mutect2, varscan2
- FAM227B | c.914T>C p.L305P | Missense Mutation (SNP) | VAF 219/541 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV54811992; called by muse, mutect2, varscan2
- FAM234B | c.1439C>T p.T480M | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as rs745677392, COSV52194470, COSV99545795; called by muse, mutect2, varscan2
- FAM3B | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 43/233 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV63613213; called by muse, mutect2, varscan2
- FAM47B | c.1733A>G p.D578G | Missense Mutation (SNP) | VAF 6/186 reads (3%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.942); catalogued as COSV100264080; called by muse, mutect2
- FAM83D | c.1165G>A p.A389T | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.091); catalogued as COSV54157599; called by muse, mutect2, varscan2
- FAM9A | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 77/219 reads (35%) | SIFT tolerated, low confidence (0.43); PolyPhen possibly damaging (0.682); catalogued as COSV66813326; called by muse, mutect2, varscan2
- FAM9A | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 62/130 reads (48%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.499); catalogued as rs1231897589, COSV66813330; called by muse, mutect2, varscan2
- FANCG | c.1619G>A p.S540N | Missense Mutation (SNP) | VAF 37/48 reads (77%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as COSV62720744; called by muse, mutect2, varscan2
- FAT1 | c.5743A>T p.I1915F | Missense Mutation (SNP) | VAF 65/155 reads (42%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV71674379; called by muse, mutect2, varscan2
- FAT1 | c.521C>T p.T174M | Missense Mutation (SNP) | VAF 81/209 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770823750, COSV71674380; called by muse, mutect2, varscan2
- FAT2 | c.7237C>T p.R2413C | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs764323221, COSV55819485; called by muse, mutect2, varscan2
- FAT2 | c.2902G>A p.A968T | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.52); PolyPhen benign (0.36); catalogued as rs149531804; called by muse, mutect2, varscan2
- FAT3 | c.4561G>A p.A1521T | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.46); PolyPhen benign (0.079); catalogued as COSV53118024; called by muse, mutect2, varscan2
- FBH1 | c.445C>T p.R149W (on ENST00000362091 / NM_178150.3; = p.R200W on NM_032807.4) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs755192280, COSV62982722; called by muse, mutect2, varscan2
- FBH1 | c.2083G>A p.V695I (on ENST00000362091 / NM_178150.3; = p.V746I on NM_032807.4) | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as rs779157463, COSV62982729; called by muse, mutect2, varscan2
- FBLN2 | c.1748C>T p.A583V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.64); PolyPhen benign (0.093); catalogued as rs370888583; called by muse, mutect2, varscan2
- FBN3 | c.1633G>A p.V545M | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as rs142269916; called by muse, mutect2, varscan2
- FBXW8 | c.1162G>T p.G388C (on ENST00000309909; = p.G426C on NM_012174.1) | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.408); catalogued as COSV99997461; called by muse, mutect2
- FCER1A | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 186/474 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.044); catalogued as COSV63667371; called by muse, mutect2, varscan2
- FCHSD2 | c.2210T>A p.I737N | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.691); catalogued as COSV60810184; called by muse, mutect2, varscan2
- FCSK | c.2923C>T p.R975C | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as rs762425961, COSV55371412; called by muse, mutect2, varscan2
- FDXR | c.559G>A p.V187M | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1344562956, COSV53122281; called by muse, mutect2, varscan2
- FGD5 | c.1420G>A p.D474N | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53243972; called by muse, mutect2, varscan2
- FGD5 | c.3779G>A p.R1260Q | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1399150810, COSV53243987; called by muse, mutect2, varscan2
- FGF5 | c.130T>C p.S44P | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.039); catalogued as COSV56890275; called by muse, mutect2, varscan2
- FGFR4 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52803205; called by muse, mutect2, varscan2
- FGFR4 | c.1832G>A p.R611Q | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1387211815, COSV52801446; called by muse, mutect2, varscan2
- FILIP1 | c.199C>T p.R67* | Nonsense Mutation (SNP) | VAF 100/236 reads (42%) | catalogued as rs905027708, COSV52725481; called by muse, mutect2, varscan2
- FIS1 | c.439G>A p.V147M | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.49); catalogued as COSV56191288; called by muse, mutect2, varscan2
- FLG2 | c.1031A>G p.N344S | Missense Mutation (SNP) | VAF 61/193 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66169112; called by muse, mutect2, varscan2
- FLNA | c.1771G>A p.V591I | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.953); catalogued as rs200673062, COSV61038114; ClinVar: likely benign; called by muse, mutect2, varscan2
- FMNL1 | c.364C>T p.R122W | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1158351749, COSV100056195; called by muse, mutect2
- FN1 | c.6871+1G>A p.X2291_splice (on ENST00000359671 / NM_001365524.2; = p.X2260_splice on NM_002026.4) | Splice Site (SNP) | VAF 110/251 reads (44%) | catalogued as rs112323657, COSV60554154; called by muse, mutect2, varscan2
- FN1 | c.3902G>A p.R1301H | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs745854917, COSV60554217; called by muse, mutect2, varscan2
- FOSL1 | c.766G>A p.G256R | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs763454407, COSV100440929, COSV57028362; called by muse, mutect2, varscan2
- FOXJ2 | c.1352C>T p.A451V | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs1472517014, COSV50819216; called by muse, mutect2, varscan2
- FOXN2 | c.1213C>T p.L405F | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61318272; called by muse, mutect2, varscan2
- FRAS1 | c.10189G>A p.D3397N | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.059); catalogued as COSV53614462, COSV53649117; called by muse, mutect2, varscan2
- FREM2 | c.7579C>T p.R2527C | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs963299361, COSV54848659, COSV99747301; called by muse, mutect2
- FRMPD2 | c.876G>A p.W292* | Nonsense Mutation (SNP) | VAF 4/55 reads (7%) | catalogued as COSV59719623; called by muse, mutect2
- FSIP1 | c.1479G>A p.M493I | Missense Mutation (SNP) | VAF 103/238 reads (43%) | SIFT tolerated (0.47); PolyPhen benign (0.013); catalogued as COSV63224968; called by muse, mutect2, varscan2
- FUBP1 | c.1575A>G p.P525= | Splice Region (SNP) | VAF 24/69 reads (35%) | catalogued as COSV53931788; called by muse, mutect2, varscan2
- FUT9 | c.515C>T p.T172M | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.042); catalogued as rs757168999, COSV56148029; called by muse, mutect2, varscan2
- FXYD5 | c.497G>A p.C166Y | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.518); catalogued as rs755638996, COSV61568842; called by mutect2, varscan2
- FYN | c.1009C>T p.P337S | Missense Mutation (SNP) | VAF 15/164 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV57618565, COSV99991171; called by muse, mutect2
- FZD2 | c.1210G>A p.V404I | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV59528462; called by muse, mutect2, varscan2
- G6PD | c.1290C>T p.N430= | Splice Region (SNP) | VAF 10/23 reads (43%) | catalogued as rs782761811, COSV100854935; called by muse, mutect2
- GAB2 | c.1256C>T p.A419V (on ENST00000361507 / NM_080491.3; = p.A381V on NM_012296.3) | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV60868260; called by muse, mutect2, varscan2
- GABPA | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 29/188 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs957953541, COSV61396369; called by muse, mutect2, varscan2
- GAK | c.1088C>T p.A363V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs577130123, COSV58505224; called by muse, mutect2, varscan2
- GAL3ST1 | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58892717; called by muse, mutect2, varscan2
- GALNT10 | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.021); catalogued as rs757748797, COSV51727339; called by muse, mutect2, varscan2
- GALNT18 | c.533T>C p.M178T | Missense Mutation (SNP) | VAF 52/99 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV57150084; called by muse, mutect2, varscan2
- GALNTL5 | c.103T>C p.W35R | Missense Mutation (SNP) | VAF 51/169 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV67179182, COSV67180265; called by muse, mutect2, varscan2
- GALR1 | c.91G>A p.V31M | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.386); catalogued as COSV55317392; called by muse, mutect2
- GAPDHS | c.1202G>A p.R401H | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.086); catalogued as COSV99382154; called by muse, varscan2
- GARS1 | c.1117C>A p.L373I | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.102); catalogued as COSV66828453; called by muse, mutect2, varscan2
- GATA5 | c.640G>A p.G214S | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782766788, COSV53346207; called by muse, mutect2, varscan2
- GBP4 | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 91/216 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs756135431, COSV63252924; called by muse, mutect2, varscan2
- GDNF | c.593A>G p.H198R | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1207487154, COSV58479757; called by muse, mutect2, varscan2
- GEN1 | c.829G>T p.G277* | Nonsense Mutation (SNP) | VAF 47/114 reads (41%) | catalogued as COSV58056790; called by muse, mutect2, varscan2
- GHR | c.1665C>G p.H555Q | Missense Mutation (SNP) | VAF 56/131 reads (43%) | SIFT tolerated (0.65); PolyPhen benign (0.044); catalogued as COSV50114250; called by muse, mutect2, varscan2
- GJA1 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.164); catalogued as rs2228961; called by muse, mutect2, varscan2
- GK5 | c.1345C>G p.Q449E | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as COSV67485839; called by muse, mutect2, varscan2
- GLI3 | c.3445C>T p.P1149S | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.041); catalogued as COSV67889154; called by muse, mutect2, varscan2
- GLMP | c.1196A>G p.Y399C | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV55295319; called by muse, mutect2
- GLRA3 | c.884C>T p.T295M | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56857865; called by muse, mutect2, varscan2
- GNAS | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.597); catalogued as COSV55673165; called by muse, mutect2, varscan2
- GNPAT | c.1846A>G p.T616A | Missense Mutation (SNP) | VAF 16/244 reads (7%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs1288273301, COSV100791555; called by muse, mutect2
- GNS | c.725C>A p.P242H | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50694834; called by muse, mutect2, varscan2
- GORASP1 | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.112); catalogued as rs1053094276, COSV56529948; called by muse, mutect2, varscan2
- GPR15 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752760213, COSV52520641, COSV52521171, COSV99423711; called by muse, mutect2, varscan2
- GPR153 | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs148779940; called by muse, mutect2, varscan2
- GPR3 | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as rs574084524, COSV64994753; called by muse, mutect2, varscan2
- GPR4 | c.496A>G p.T166A | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.625); catalogued as COSV59917208; called by muse, mutect2, varscan2
- GPRC5B | c.1147G>A p.V383I | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs751771117, COSV56026701; called by muse, mutect2, varscan2
- GPS1 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.106); catalogued as rs749863538, COSV57648122; called by muse, mutect2, varscan2
- GRIA3 | c.2176C>T p.R726* | Nonsense Mutation (SNP) | VAF 31/82 reads (38%) | catalogued as COSV52058496; called by muse, mutect2, varscan2
- GRID2 | c.2303G>A p.R768Q | Missense Mutation (SNP) | VAF 137/482 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as rs758779402, COSV56175461; called by muse, mutect2, varscan2
- GRIK3 | c.955A>G p.M319V | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.456); catalogued as COSV66140519; called by muse, mutect2, varscan2
- GRIK3 | c.829G>A p.V277M | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs749738235, COSV66140529; called by muse, mutect2, varscan2
- GRIN2D | c.2182G>A p.D728N | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.47); catalogued as rs752367785, COSV54379307; called by muse, mutect2, varscan2
- GSDMC | c.19C>T p.R7C | Missense Mutation (SNP) | VAF 51/126 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.048); catalogued as rs369692449, COSV52695873, COSV52696298; called by muse, mutect2, varscan2
- GSTM5 | c.111C>T p.D37= | Splice Region (SNP) | VAF 4/58 reads (7%) | catalogued as rs1276733007, COSV99859808; called by muse, mutect2
- GTF2B | c.862T>C p.S288P | Missense Mutation (SNP) | VAF 80/242 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as COSV65137002; called by muse, mutect2, varscan2
- GTF2IRD1 | c.2710C>T p.R904W (on ENST00000265755 / NM_016328.3; = p.R889W on NM_005685.4) | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs782283712, COSV56084743; called by muse, mutect2, varscan2
- GTPBP2 | c.1409G>A p.R470Q | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.061); catalogued as rs889848479, COSV61076271; called by muse, mutect2, varscan2
- GYS2 | c.1864C>T p.H622Y | Missense Mutation (SNP) | VAF 24/310 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.334); catalogued as COSV53924952; called by muse, mutect2
- HADHA | c.1297C>T p.L433F | Missense Mutation (SNP) | VAF 21/268 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV101023744; called by muse, mutect2
- HAUS2 | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 77/180 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as rs777814162, COSV53000233; called by muse, mutect2, varscan2
- HAUS5 | c.1448T>C p.L483P | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52548130; called by muse, mutect2, varscan2
- HEATR4 | c.1483C>T p.R495W | Missense Mutation (SNP) | VAF 63/145 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777866454, COSV58573115; called by muse, mutect2, varscan2
- HECTD3 | c.1829G>A p.R610Q | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1294307486, COSV64670261; called by muse, mutect2, varscan2
- HECTD4 | c.9074G>A p.R3025H | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.944); catalogued as rs1041326557, COSV66392783; called by muse, mutect2, varscan2
- HERC1 | c.6285G>A p.W2095* | Nonsense Mutation (SNP) | VAF 45/200 reads (23%) | catalogued as COSV71248034; called by muse, mutect2, varscan2
- HERC2 | c.7351C>T p.R2451C | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.265); catalogued as rs747158925, COSV55326288; called by muse, mutect2, varscan2
- HERC4 | c.1286C>T p.T429M | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.255); catalogued as rs775231001, COSV53271886; called by muse, mutect2, varscan2
- HGSNAT | c.1420C>A p.L474M | Missense Mutation (SNP) | VAF 100/244 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV52817298; called by muse, mutect2, varscan2
- HHIPL2 | c.1885G>A p.A629T | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as rs774697746, COSV58564862, COSV58565498; called by muse, mutect2, varscan2
- HIP1R | c.1298G>A p.R433H | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.15); catalogued as rs1286978062, COSV53441895; called by muse, mutect2, varscan2
- HIVEP1 | c.3326C>T p.S1109L | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.86); catalogued as rs749443605, COSV65101998; called by muse, mutect2, varscan2
- HIVEP2 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 67/172 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs773500636, COSV50015099; called by muse, mutect2, varscan2
- HIVEP3 | c.2965C>T p.R989W | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99911550; called by muse, mutect2
- HLTF | c.1694C>T p.P565L | Missense Mutation (SNP) | VAF 22/410 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100026729; called by muse, mutect2
- HNRNPM | c.415G>A p.G139R | Missense Mutation (SNP) | VAF 91/217 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs770428991, COSV57692818; called by muse, mutect2, varscan2
- HNRNPUL1 | c.818C>T p.P273L | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.586); catalogued as rs1274808146, COSV99646917; called by muse, mutect2, varscan2
- HOOK3 | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 131/336 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.017); catalogued as rs373212244; called by muse, mutect2, varscan2
- HOXA11 | c.64G>A p.V22I | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as rs748711854, COSV50053212; called by muse, mutect2, varscan2
- HRH2 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.274); catalogued as rs749818733, COSV51574492; called by muse, mutect2, varscan2
- HS3ST5 | c.61G>A p.V21I | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0); catalogued as rs563950628, COSV57141864; called by muse, mutect2, varscan2
- ICAM2 | c.322G>A p.V108M | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.836); catalogued as rs778683888, COSV56743633; called by muse, mutect2, varscan2
- ICE2 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 8/241 reads (3%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as rs1338559184, COSV99831296; called by muse, mutect2
- ID2 | c.203T>C p.V68A | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1370311207, COSV52170088; called by muse, mutect2, varscan2
- IDUA | c.1838C>T p.A613V | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs780813368, COSV56103610; called by mutect2, varscan2
- IFT172 | c.437C>A p.S146Y | Missense Mutation (SNP) | VAF 131/331 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.89); catalogued as COSV53134327, COSV53140652; called by muse, mutect2, varscan2
- IFT80 | c.1006A>G p.R336G | Missense Mutation (SNP) | VAF 57/162 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs775835775, COSV58448053; called by muse, mutect2, varscan2
- IGDCC4 | c.3632C>T p.P1211L | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs560887461, COSV61537226; called by muse, mutect2, varscan2
- IGF1R | c.401G>T p.R134M | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.054); catalogued as COSV99148858; called by mutect2, varscan2
- IGHG4 | c.233C>T p.T78M | Missense Mutation (SNP) | VAF 98/356 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as rs369733387; called by muse, mutect2, varscan2
- IGLV2-18 | c.109G>A p.V37I | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.062); catalogued as rs976650386; called by muse, mutect2, varscan2
- IGSF10 | c.3688del p.S1230Afs*4 | Frame Shift Del (DEL) | VAF 150/479 reads (31%) | catalogued as rs36002001; called by mutect2, pindel, varscan2
- IGSF9 | c.2926T>C p.S976P (on ENST00000368094 / NM_001135050.2; = p.S960P on NM_020789.4) | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100230968; called by muse, mutect2, varscan2
- IKBKB | c.625G>A p.G209S | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs879530394, COSV60597568; called by muse, mutect2, varscan2
- IL17RA | c.762+2T>C p.X254_splice | Splice Site (SNP) | VAF 50/117 reads (43%) | catalogued as rs768313727, COSV60053741; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1925G>A p.C642Y | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV100780746; called by muse, mutect2
- IL31RA | c.2134C>T p.R712C | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs748001461, COSV61694232; called by muse, mutect2, varscan2
- ILF3 | c.2042C>T p.S681L | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs778052848, COSV51558337; called by muse, mutect2, varscan2
- ING1 | c.703G>A p.V235M | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV58166474; called by muse, mutect2, varscan2
- INPPL1 | c.3577G>A p.A1193T | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.027); catalogued as COSV53356003; called by muse, mutect2, varscan2
- INSRR | c.2582C>T p.T861I | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.761); catalogued as COSV63873725; called by muse, mutect2, varscan2
- INTS11 | c.1528C>T p.R510C | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV100028020; called by muse, mutect2
- INTS8 | c.2774T>A p.M925K | Missense Mutation (SNP) | VAF 146/373 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV57376239; called by muse, mutect2, varscan2
- IPO5 | c.2209C>T p.R737C | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs1383579161, COSV55154409; called by muse, mutect2
- IPP | c.511A>G p.S171G | Missense Mutation (SNP) | VAF 24/234 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100739392; called by muse, mutect2, varscan2
- IQCF2 | c.205A>G p.R69G | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as rs375563868; called by muse, mutect2, varscan2
- IQSEC3 | c.2258G>A p.R753Q (on ENST00000538872 / NM_001170738.2; = p.R450Q on NM_015232.1) | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs527558225, COSV58285414; called by muse, mutect2, varscan2
- IRS4 | c.1772del p.G591Afs*20 | Frame Shift Del (DEL) | VAF 42/136 reads (31%) | catalogued as rs780982673; called by mutect2, varscan2
- IRX1 | c.1204C>T p.H402Y | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV57357948, COSV57359744; called by muse, mutect2, varscan2
- ISG20L2 | c.197C>T p.T66M | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.083); catalogued as rs759960220, COSV57460376; called by muse, mutect2, varscan2
- ISOC1 | c.257G>A p.G86D | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.992); catalogued as COSV51491898; called by muse, mutect2, varscan2
- ITGAE | c.125T>C p.L42P | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV53994788, COSV54000507; called by muse, mutect2, varscan2
- ITGB4 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.57); PolyPhen benign (0.081); catalogued as rs747831589, COSV52325433; called by muse, mutect2, varscan2
- ITPKC | c.1804C>T p.L602F | Missense Mutation (SNP) | VAF 7/153 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV99648476; called by muse, mutect2
- JADE2 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.49); catalogued as rs759883080, COSV50917540; called by muse, mutect2, varscan2
- JAG2 | c.3673G>A p.A1225T | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.8); PolyPhen benign (0.005); catalogued as rs140910378; called by muse, varscan2
- JCAD | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as rs776114200, COSV64759912; called by muse, mutect2, varscan2
- JMJD1C | c.6623C>T p.A2208V | Missense Mutation (SNP) | VAF 78/191 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.273); catalogued as rs201993291, COSV59514471; called by muse, mutect2, varscan2
- JMJD1C | c.2804C>T p.P935L | Missense Mutation (SNP) | VAF 111/228 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as rs1421416607, COSV59515250; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KALRN | c.2437C>T p.R813C | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); catalogued as rs758760625, COSV53761733; called by muse, mutect2, varscan2
- KANSL1 | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756749550, COSV52269926, COSV99294093; ClinVar: likely benign; called by muse, mutect2
- KAT2B | c.2381G>A p.R794Q | Missense Mutation (SNP) | VAF 96/234 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1429314008, COSV55429924; called by muse, mutect2, varscan2
- KAT6B | c.3719A>G p.E1240G | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.968); catalogued as COSV54747495; called by muse, mutect2, varscan2
- KAT8 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54896227, COSV99571049; called by muse, mutect2, varscan2
- KCMF1 | c.22A>G p.S8G | Missense Mutation (SNP) | VAF 90/210 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV69053867, COSV69054134; called by muse, mutect2, varscan2
- KCNA6 | c.1406C>T p.T469M | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.407); catalogued as rs770437452, COSV54975582; called by muse, mutect2, varscan2
- KCNMB3 | c.52C>T p.R18C | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs764992727, COSV62895395; called by muse, mutect2, varscan2
- KCNN4 | c.1166A>G p.H389R | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.715); catalogued as COSV53455719; called by muse, mutect2, varscan2
- KCNQ2 | c.880G>C p.A294P | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV60434572; called by muse, mutect2, varscan2
- KCNQ5 | c.2078C>T p.T693M | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as rs777062053, COSV59649876; called by muse, mutect2, varscan2
- KDF1 | c.704C>T p.S235L | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.361); catalogued as rs371743170; called by muse, mutect2, varscan2
- KDM5B | c.2009G>A p.R670H | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0.012); catalogued as rs1336954577, COSV52508337; called by muse, mutect2, varscan2
- KDM6B | c.4384G>A p.V1462M | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1256209302, COSV54682026; called by muse, mutect2, varscan2
- KDR | c.3121G>A p.V1041M | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs922679946, COSV55766734; called by muse, mutect2
- KEL | c.106G>A p.V36M | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs373423972; called by muse, mutect2, varscan2
- KHSRP | c.829A>G p.T277A | Missense Mutation (SNP) | VAF 7/174 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.57); catalogued as COSV101231133; called by muse, mutect2
- KIAA1109 | c.7718G>A p.R2573H | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52675317; called by muse, mutect2, varscan2
- KIAA1109 | c.10345G>A p.V3449I | Missense Mutation (SNP) | VAF 20/179 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.972); catalogued as rs374152682, COSV52675329; called by muse, mutect2, varscan2
- KIAA1755 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as rs769949948, COSV99641491; called by muse, mutect2
- KIF1B | c.5407C>T p.R1803W (on ENST00000377086 / NM_001365952.1; = p.R1757W on NM_015074.3) | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759957126, COSV55809487; called by muse, mutect2, varscan2
- KIF21A | c.4124T>C p.V1375A (on ENST00000361418 / NM_001378440.1; = p.V1362A on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/150 reads (41%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.995); catalogued as COSV62772052; called by muse, mutect2, varscan2
- KIF26B | c.1991G>A p.R664H | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774587685, COSV63642567; called by muse, mutect2, varscan2
- KIF7 | c.1903C>T p.R635W | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.63); catalogued as rs150543610; called by muse, mutect2, varscan2
- KIRREL2 | c.379del p.Q127Rfs*18 | Frame Shift Del (DEL) | VAF 26/65 reads (40%) | catalogued as rs758018108; called by mutect2, pindel, varscan2
- KLF17 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs147552179; called by muse, mutect2, varscan2
- KLF3 | c.194C>T p.T65M | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV54710978; called by muse, mutect2, varscan2
- KLHL10 | c.1460G>A p.G487D | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53173334; called by muse, mutect2, varscan2
- KLHL13 | c.769C>T p.L257F | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53248460; called by muse, mutect2, varscan2
- KLHL13 | c.283A>G p.T95A | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.089); catalogued as COSV53248485; called by muse, mutect2, varscan2
- KLHL14 | c.1384G>A p.A462T | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.992); catalogued as COSV100839060; called by muse, mutect2
- KLHL17 | c.976G>A p.V326I | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs373273289; called by muse, mutect2, varscan2
- KLHL23 | c.826T>C p.Y276H | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.378); catalogued as rs770870100, COSV55867432; called by muse, mutect2, varscan2
- KLHL40 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV55134784; called by muse, mutect2, varscan2
- KLK2 | c.608C>T p.T203I | Missense Mutation (SNP) | VAF 89/177 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as COSV57569736; called by muse, mutect2, varscan2
- KMT2A | c.3619C>T p.Q1207* | Nonsense Mutation (SNP) | VAF 146/370 reads (39%) | catalogued as COSV63286247; called by muse, varscan2
- KMT2C | c.13040C>T p.P4347L | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.632); catalogued as rs1019760354, COSV51445129; called by muse, mutect2, varscan2
- KMT2C | c.7825C>T p.R2609* | Nonsense Mutation (SNP) | VAF 4/68 reads (6%) | catalogued as COSV51419035; called by muse, mutect2
- KMT2C | c.5716C>T p.R1906* | Nonsense Mutation (SNP) | VAF 29/69 reads (42%) | catalogued as rs763438739, COSV51279719, COSV51462477; called by muse, mutect2, varscan2
- KMT2E | c.1846T>C p.C616R | Missense Mutation (SNP) | VAF 68/177 reads (38%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.416); catalogued as COSV57573928; called by muse, mutect2, varscan2
- KREMEN1 | c.694G>A p.D232N (on ENST00000407188; = p.D234N on NM_032045.5) | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs748122732, COSV59913049; called by muse, mutect2, varscan2
- KRT12 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.508); catalogued as COSV52430983; called by muse, mutect2
- KRT14 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.615); catalogued as COSV51421496, COSV51421546; called by muse, mutect2, varscan2
- KRT14 | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.46); catalogued as rs1328900707, COSV51421510; called by muse, mutect2, varscan2
- KRT34 | c.208G>A p.G70S | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0.006); catalogued as rs778666078, COSV101222678, COSV67449900; called by muse, mutect2, varscan2
- KRT39 | c.1250A>G p.E417G | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.065); catalogued as COSV62917354; called by muse, mutect2, varscan2
- KRT6B | c.472C>T p.R158W | Missense Mutation (SNP) | VAF 75/271 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as rs537928073, COSV52882215, COSV52883185; called by muse, mutect2, varscan2
- KRTAP9-2 | c.115C>T p.Q39* | Nonsense Mutation (SNP) | VAF 42/148 reads (28%) | catalogued as COSV66646713; called by muse, mutect2, varscan2
- L1CAM | c.2413G>A p.G805S | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62828292; called by muse, mutect2, varscan2
- L3MBTL1 | c.2288C>T p.A763V (on ENST00000418998 / NM_001377303.1; = p.A673V on NM_015478.7) | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1030340944, COSV64228659; called by muse, mutect2, varscan2
- LAMB4 | c.5013A>C p.K1671N | Missense Mutation (SNP) | VAF 87/422 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV52720475; called by muse, mutect2, varscan2
- LAMB4 | c.533T>C p.V178A | Missense Mutation (SNP) | VAF 89/201 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as rs770651993, COSV52720485; called by muse, mutect2, varscan2
- LAPTM4A | c.520A>G p.I174V | Missense Mutation (SNP) | VAF 52/148 reads (35%) | SIFT tolerated (0.85); PolyPhen benign (0.005); catalogued as rs142563595; called by muse, mutect2, varscan2
- LARP4B | c.1924G>A p.A642T | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs200550169; called by mutect2, varscan2
- LARP7 | c.679C>T p.R227* | Nonsense Mutation (SNP) | VAF 82/236 reads (35%) | catalogued as rs775430086, COSV60521110; called by muse, mutect2, varscan2
- LCN10 | c.152C>T p.T51I | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.682); catalogued as COSV57910601; called by muse, mutect2, varscan2
- LCN6 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV57910057, COSV57910613; called by muse, mutect2, varscan2
- LCP2 | c.1528C>G p.L510V | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99252120; called by muse, mutect2
- LIMCH1 | c.2443C>T p.R815C | Missense Mutation (SNP) | VAF 67/177 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756189356, COSV58284897; called by muse, mutect2, varscan2
- LIN54 | c.1517G>A p.R506Q | Missense Mutation (SNP) | VAF 85/228 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.86); catalogued as rs780125139, COSV61199773; called by muse, mutect2, varscan2
- LINGO3 | c.1037C>T p.T346M | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as COSV101347210; called by mutect2, varscan2
- LIPE | c.856C>T p.R286W | Missense Mutation (SNP) | VAF 64/150 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.075); catalogued as rs1364703014, COSV54923133; called by muse, mutect2, varscan2
- LLGL1 | c.1982G>A p.R661H | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs138562673; called by muse, mutect2, varscan2
- LLGL2 | c.2287G>T p.E763* | Nonsense Mutation (SNP) | VAF 4/13 reads (31%) | catalogued as COSV51356152; called by muse, mutect2, varscan2
- LMNTD2 | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs754636615, COSV54241745; called by muse, mutect2, varscan2
- LMOD1 | c.1405C>T p.R469C | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770962428, COSV66172823; called by muse, mutect2, varscan2
- LNP1 | c.387+2T>C p.X129_splice | Splice Site (SNP) | VAF 23/115 reads (20%) | catalogued as rs1249779415, COSV67346771; called by muse, mutect2, varscan2
- LONP2 | c.898dup p.M300Nfs*12 | Frame Shift Ins (INS) | VAF 66/176 reads (38%) | catalogued as rs745798174; called by mutect2, varscan2
- LPAR1 | c.484C>T p.R162W | Missense Mutation (SNP) | VAF 44/68 reads (65%) | SIFT tolerated (0.06); PolyPhen benign (0.398); catalogued as rs755789465, COSV62689039; called by muse, mutect2, varscan2
- LPIN3 | c.1399C>A p.L467I | Missense Mutation (SNP) | VAF 49/120 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as rs988127379, COSV64718551; called by muse, mutect2, varscan2
- LRIG1 | c.1693C>T p.R565C | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.975); catalogued as rs747020747, COSV56240773; called by muse, mutect2, varscan2
- LRR1 | c.502C>T p.R168* | Nonsense Mutation (SNP) | VAF 15/141 reads (11%) | catalogued as rs377149462; called by muse, mutect2, varscan2
- LRRC47 | c.916C>T p.R306W | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs200783146; called by muse, mutect2, varscan2
- LRRTM1 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs748970613, COSV54441193, COSV99703120; called by muse, mutect2, varscan2
- LSM4 | c.325C>T p.R109* | Nonsense Mutation (SNP) | VAF 5/16 reads (31%) | catalogued as rs1207428956, COSV53253716; called by muse, mutect2, varscan2
- LTBP2 | c.2212C>T p.R738C | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773189908, COSV56208806; called by muse, mutect2, varscan2
- LY75 | c.1954G>A p.A652T | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs371478963; called by muse, mutect2, varscan2
- MAGEA6 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 107/242 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as rs782683188, COSV100262881, COSV61449035; called by muse, mutect2, varscan2
- MAGEB6 | c.170A>G p.D57G | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs1435965938, COSV66872352; called by muse, mutect2, varscan2
- MAGEC3 | c.179G>T p.R60M | Missense Mutation (SNP) | VAF 77/253 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); catalogued as COSV53581003; called by muse, mutect2, varscan2
- MAGED2 | c.1166C>A p.A389D | Missense Mutation (SNP) | VAF 20/402 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.262); catalogued as COSV99514383; called by muse, mutect2
- MAGI1 | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 72/157 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.124); catalogued as rs143246754; called by muse, mutect2, varscan2
- MANEA | c.1168C>G p.L390V | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.088); catalogued as rs747405720, COSV62589761; called by muse, mutect2, varscan2
- MAP1LC3B | c.61C>T p.R21* | Nonsense Mutation (SNP) | VAF 50/193 reads (26%) | catalogued as rs1326393090, COSV51784779; called by muse, mutect2, varscan2
- MAP2 | c.3768G>C p.Q1256H | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); catalogued as COSV99557977; called by muse, mutect2
- MAP2 | c.4613G>A p.R1538H | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs200474600, COSV52289471; called by muse, mutect2, varscan2
- MAP3K15 | c.1481G>A p.R494H | Missense Mutation (SNP) | VAF 64/135 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs369494074, COSV58826955; called by muse, mutect2, varscan2
- MAP3K4 | c.3212G>A p.R1071Q | Missense Mutation (SNP) | VAF 36/245 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.029); catalogued as rs199868127, COSV62334217; called by muse, mutect2, varscan2
- MAP3K7 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs1157398284, COSV65224632; called by muse, mutect2, varscan2
- MAP3K7 | c.269T>C p.V90A | Missense Mutation (SNP) | VAF 87/207 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV65232001, COSV65233416; called by muse, mutect2, varscan2
- MAP7D1 | c.1693G>A p.A565T | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV60216589; called by muse, mutect2, varscan2
- MAP7D2 | c.1550A>G p.E517G | Missense Mutation (SNP) | VAF 129/302 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.519); catalogued as COSV65527626; called by muse, mutect2, varscan2
- MAP7D3 | c.1432C>T p.Q478* | Nonsense Mutation (SNP) | VAF 86/213 reads (40%) | catalogued as rs1435383856, COSV60171101; called by muse, mutect2, varscan2
- MAPK10 | c.707A>G p.K236R (on ENST00000359221 / NM_001351625.2; = p.K274R on NM_002753.5) | Missense Mutation (SNP) | VAF 83/234 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.331); catalogued as COSV60383422; called by muse, mutect2, varscan2
- MAPK8IP3 | c.3316C>T p.R1106C | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1330820829, COSV51600868; called by muse, mutect2, varscan2
- MAPT | c.2312G>A p.R771H (on ENST00000262410 / NM_001377265.1; = p.R379H on NM_005910.5) | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1568347450, COSV52240871; called by muse, mutect2, varscan2
- MARCO | c.1558G>A p.V520I | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.198); catalogued as rs200590124; called by muse, mutect2, varscan2
- MARF1 | c.3338G>A p.S1113N | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as COSV60024102; called by muse, mutect2, varscan2
- MARS2 | c.949G>A p.A317T | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV56571443; called by muse, mutect2, varscan2
- MBNL1 | c.836G>A p.R279Q | Missense Mutation (SNP) | VAF 80/169 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.721); catalogued as rs760190490, COSV56829059; called by muse, mutect2, varscan2
- MDC1 | c.3160A>G p.N1054D | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.062); catalogued as COSV64524860; called by muse, mutect2, varscan2
- MDGA1 | c.661G>A p.V221M | Missense Mutation (SNP) | VAF 46/95 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs768884775, COSV51796444; called by muse, mutect2, varscan2
- MDN1 | c.12338G>A p.R4113Q | Missense Mutation (SNP) | VAF 87/240 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs371690614, COSV65533733; called by muse, mutect2, varscan2
- MDN1 | c.9853G>A p.V3285I | Missense Mutation (SNP) | VAF 62/149 reads (42%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs757242302, COSV65522487; called by muse, mutect2, varscan2
- MDN1 | c.8540G>A p.R2847H | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.759); catalogued as rs150701881; called by muse, mutect2, varscan2
- MECOM | c.2249G>A p.R750Q (on ENST00000468789 / NM_001105078.4; = p.R938Q on NM_004991.4) | Missense Mutation (SNP) | VAF 22/194 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV52961254; called by muse, mutect2, varscan2
- MED14 | c.1603A>G p.K535E | Missense Mutation (SNP) | VAF 161/438 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV61357006; called by muse, mutect2, varscan2
- MEGF10 | c.2792A>G p.H931R | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as COSV57249917; called by muse, mutect2, varscan2
- MEGF8 | c.4136C>T p.A1379V (on ENST00000251268 / NM_001271938.2; = p.A1312V on NM_001410.3) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1156901466, COSV52086926; called by muse, mutect2, varscan2
- MEN1 | c.613G>A p.G205S | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53643799, COSV99581341; called by muse, mutect2, varscan2
- MEX3C | c.1088C>T p.P363L | Missense Mutation (SNP) | VAF 55/113 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1175092893, COSV68529968; called by muse, mutect2, varscan2
- MFSD10 | c.674C>T p.T225M | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs780458416, COSV53269687; called by muse, mutect2, varscan2
- MFSD14A | c.851C>T p.A284V | Missense Mutation (SNP) | VAF 199/457 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.036); catalogued as rs1402692712, COSV64514700; called by muse, mutect2, varscan2
- MGA | c.2596C>T p.R866* | Nonsense Mutation (SNP) | VAF 82/181 reads (45%) | catalogued as COSV54949467; called by muse, mutect2, varscan2
- MGA | c.8579G>A p.R2860Q (on ENST00000219905 / NM_001164273.1; = p.R2651Q on NM_001080541.2) | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs773151185, COSV54948033, COSV54955101; called by muse, mutect2, varscan2
- MIB1 | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs750577728; called by muse, mutect2, varscan2
- MIOS | c.1034G>A p.R345Q | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.717); catalogued as COSV60768060; called by muse, mutect2, varscan2
- MKI67 | c.1576C>T p.P526S | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100896189; called by muse, mutect2
- MLNR | c.971C>T p.T324M | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs1034861747, COSV99519668; called by muse, mutect2
- MMP14 | c.1222C>T p.R408* | Nonsense Mutation (SNP) | VAF 56/144 reads (39%) | catalogued as COSV61288502; called by muse, mutect2, varscan2
- MMS19 | c.2467C>T p.R823W | Missense Mutation (SNP) | VAF 52/156 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs144416594, COSV59135362; called by muse, mutect2, varscan2
- MOCOS | c.2014C>T p.R672C | Missense Mutation (SNP) | VAF 106/277 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs570246282, COSV54341597; called by muse, mutect2
- MON2 | c.1900+2T>C p.X634_splice | Splice Site (SNP) | VAF 39/133 reads (29%) | catalogued as COSV54808147; called by muse, mutect2, varscan2
- MPP2 | c.1315C>T p.R439C (on ENST00000461854 / NM_001278372.2; = p.R415C on NM_005374.5) | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs199836068; called by muse, mutect2, varscan2
- MRGPRD | c.136A>G p.S46G | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs776075795, COSV58423273, COSV58423974; called by muse, mutect2, varscan2
- MRPL28 | c.418G>A p.G140R | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756831724, COSV51739641; called by muse, mutect2, varscan2
- MRPL32 | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.398); catalogued as rs780282413, COSV56237828; called by muse, mutect2, varscan2
- MRPL49 | c.85A>G p.T29A | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV99588974; called by muse, mutect2
- MRPL49 | c.286G>A p.V96I | Missense Mutation (SNP) | VAF 65/154 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.583); catalogued as rs539335985, COSV53695611; called by muse, varscan2
- MRPL50 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 60/89 reads (67%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.938); catalogued as rs143180617; called by muse, mutect2, varscan2
- MST1R | c.1408C>T p.R470C | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs757151241, COSV56566989; called by muse, mutect2, varscan2
- MSTN | c.218G>A p.S73N | Missense Mutation (SNP) | VAF 98/337 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV53621098; called by muse, mutect2, varscan2
- MTA1 | c.1804C>T p.P602S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as rs1555432992, COSV58757557; called by muse, mutect2, varscan2
- MTF1 | c.1142C>T p.T381M | Missense Mutation (SNP) | VAF 96/214 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.253); catalogued as rs763643120, COSV65989306; called by muse, mutect2, varscan2
- MTMR10 | c.1199T>C p.V400A | Missense Mutation (SNP) | VAF 52/512 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as COSV100075917; called by muse, mutect2
- MTMR7 | c.296G>A p.R99H | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.188); catalogued as rs55985080, COSV99471970; called by muse, mutect2, varscan2
- MTSS1 | c.1400C>A p.T467N | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV61497357; called by muse, mutect2, varscan2
- MTTP | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 55/127 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as rs201464944; called by muse, mutect2, varscan2
- MTUS2 | c.1997G>T p.G666V | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV70917068; called by muse, mutect2, varscan2
- MUC16 | c.37688G>A p.R12563H | Missense Mutation (SNP) | VAF 135/355 reads (38%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0); catalogued as rs745990384, COSV67469400; called by muse, mutect2, varscan2
- MUC16 | c.4682C>T p.T1561M | Missense Mutation (SNP) | VAF 170/396 reads (43%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as rs199772369; called by muse, mutect2, varscan2
- MUC2 | c.1204G>A p.V402I | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.13); catalogued as COSV61244645; called by muse, mutect2, varscan2
- MUL1 | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV51641003; called by muse, mutect2, varscan2
- MUSK | c.2560C>T p.R854* | Nonsense Mutation (SNP) | VAF 11/20 reads (55%) | catalogued as rs764615519, COSV51892336; called by muse, mutect2
- MYCBPAP | c.1730C>A p.P577H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60408401; called by muse, mutect2, varscan2
- MYH10 | c.5215G>A p.A1739T | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.053); catalogued as rs767265670, COSV52602402; called by muse, mutect2, varscan2
- MYH10 | c.1339A>G p.T447A | Missense Mutation (SNP) | VAF 51/142 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.728); catalogued as COSV52602427; called by muse, mutect2, varscan2
- MYH7B | c.286G>A p.G96R | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs752767629, COSV53420627; called by muse, mutect2, varscan2
- MYO15A | c.3988C>T p.R1330C | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374131038; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO18B | c.2507C>T p.A836V | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs772478099, COSV59135764; called by muse, mutect2, varscan2
- MYO1F | c.1675G>A p.A559T | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs900337903, COSV57795669; called by muse, mutect2, varscan2
- MYO1G | c.1351G>A p.A451T | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.166); catalogued as rs1042764007, COSV99348479; called by muse, mutect2, varscan2
- MYO7A | c.3235G>A p.G1079S | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.935); catalogued as COSV68684900; called by muse, mutect2, varscan2
- MYO9A | c.4849G>A p.V1617I | Missense Mutation (SNP) | VAF 93/241 reads (39%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as COSV61851775; called by muse, mutect2, varscan2
- MYOF | c.5960G>A p.R1987Q | Missense Mutation (SNP) | VAF 37/220 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs755367267, COSV63704847, COSV63709503; called by muse, mutect2, varscan2
- MYPN | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1473380971, COSV62734517; called by muse, mutect2, varscan2
- N6AMT1 | c.557T>C p.M186T | Missense Mutation (SNP) | VAF 112/279 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV58134561; called by muse, mutect2, varscan2
- NAA60 | c.307G>A p.V103I | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs779804473, COSV62654896; called by muse, mutect2, varscan2
- NAMPT | c.238A>G p.I80V | Missense Mutation (SNP) | VAF 48/598 reads (8%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.94); catalogued as COSV99747655; called by muse, mutect2
- NAV1 | c.1025C>T p.T342M | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.42); catalogued as COSV55218299; called by muse, mutect2, varscan2
- NAV1 | c.4222G>T p.D1408Y | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.611); catalogued as COSV55218310; called by muse, mutect2, varscan2
- NBEA | c.4094C>T p.S1365F | Missense Mutation (SNP) | VAF 15/207 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as COSV100077001; called by muse, mutect2
- NBPF10 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 80/518 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.163); catalogued as COSV100744119; called by muse, mutect2, varscan2
- NCAM2 | c.2132C>T p.A711V | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT tolerated (0.93); PolyPhen benign (0.005); catalogued as COSV99521402; called by muse, mutect2
- NCBP1 | c.1228G>A p.V410I | Missense Mutation (SNP) | VAF 44/62 reads (71%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV64316825; called by muse, mutect2, varscan2
- NCBP3 | c.1400G>A p.R467Q | Missense Mutation (SNP) | VAF 113/269 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs756290280, COSV50107525; called by muse, mutect2, varscan2
- NCKIPSD | c.2062C>T p.R688* | Nonsense Mutation (SNP) | VAF 57/124 reads (46%) | catalogued as rs1412910312, COSV53661260; called by muse, mutect2, varscan2
- NCOA1 | c.253C>T p.Q85* | Nonsense Mutation (SNP) | VAF 55/137 reads (40%) | catalogued as COSV56044971; called by muse, mutect2, varscan2
- NCOR1 | c.5848C>T p.R1950C | Missense Mutation (SNP) | VAF 9/214 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51962914; called by muse, mutect2
- NDC80 | c.1726C>T p.R576* | Nonsense Mutation (SNP) | VAF 52/126 reads (41%) | catalogued as rs142173030, COSV99859564; called by muse, mutect2, varscan2
- NDST3 | c.1445A>G p.H482R | Missense Mutation (SNP) | VAF 65/186 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs753438148, COSV56619811; called by muse, mutect2, varscan2
- NDUFAF1 | c.790C>T p.R264* | Nonsense Mutation (SNP) | VAF 8/74 reads (11%) | catalogued as rs765203135, COSV52975504; called by mutect2, varscan2
- NDUFB8 | c.312G>A p.P104= | Splice Region (SNP) | VAF 44/114 reads (39%) | catalogued as rs368053910, COSV100144019; called by muse, mutect2, varscan2
- NDUFS2 | c.880C>T p.R294W | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760084003, COSV57155020; called by muse, mutect2, varscan2
- NEB | c.3665C>T p.A1222V | Missense Mutation (SNP) | VAF 104/279 reads (37%) | SIFT tolerated (1); PolyPhen probably damaging (0.995); catalogued as COSV51421255; called by muse, mutect2, varscan2
- NECTIN3 | c.193C>T p.H65Y | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV60551604; called by muse, mutect2, varscan2
- NEDD4 | c.2488C>T p.Q830* (on ENST00000508342 / NM_001284338.1; = p.Q411* on NM_006154.4) | Nonsense Mutation (SNP) | VAF 17/153 reads (11%) | catalogued as COSV59062298; called by muse, mutect2, varscan2
- NEDD9 | c.2251C>A p.L751I | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65221416; called by muse, mutect2, varscan2
- NEK2 | c.1327G>T p.G443C | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV65356097; called by muse, mutect2, varscan2
- NELL2 | c.2008G>A p.V670I | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.979); catalogued as rs747987094, COSV61575958; called by muse, mutect2, varscan2
- NEPRO | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 28/252 reads (11%) | SIFT tolerated (0.85); PolyPhen benign (0.11); catalogued as rs148625108; called by muse, mutect2, varscan2
- NEUROD1 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54549525; called by muse, mutect2, varscan2
- NF1 | c.4639G>T p.G1547C (on ENST00000358273 / NM_001042492.3; = p.G1526C on NM_000267.3) | Missense Mutation (SNP) | VAF 9/154 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100646067; called by muse, mutect2
- NFIL3 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52683753; called by muse, mutect2
- NFIX | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771724729, COSV62176294, COSV62177672; called by muse, mutect2, varscan2
- NHS | c.1685G>A p.R562H | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.966); catalogued as rs143289369, COSV66275679; called by muse, mutect2, varscan2
- NID2 | c.2515C>T p.R839W | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.586); catalogued as rs764037512, COSV53495139; called by muse, mutect2, varscan2
- NIPBL | c.1091G>A p.R364H | Missense Mutation (SNP) | VAF 88/197 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV56952557; called by muse, mutect2, varscan2
- NIPBL | c.7220G>A p.R2407Q | Missense Mutation (SNP) | VAF 79/173 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM148618, COSV56952574; called by muse, mutect2, varscan2
- NKTR | c.3550G>A p.E1184K | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.137); catalogued as rs778803693, COSV51770505; called by muse, mutect2, varscan2
- NLE1 | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs748512588, COSV100680834, COSV62604297; called by muse, mutect2, varscan2
- NMD3 | c.1369A>G p.N457D | Missense Mutation (SNP) | VAF 30/323 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.955); catalogued as rs1483438365, COSV100664608; called by muse, mutect2
- NOBOX | c.611G>T p.G204V | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV56194866, COSV56198183; called by muse, mutect2, varscan2
- NOD1 | c.1970G>A p.R657H | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs554191049, COSV56112762; called by muse, mutect2, varscan2
- NOMO1 | c.1163C>T p.T388M | Missense Mutation (SNP) | VAF 186/485 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs757016366, COSV55058744; called by muse, mutect2, varscan2
- NOTCH3 | c.3632C>T p.S1211L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV54636179; called by muse, mutect2, varscan2
- NPHP3 | c.2851C>T p.R951* | Nonsense Mutation (SNP) | VAF 28/87 reads (32%) | catalogued as rs148670389; called by muse, mutect2, varscan2
- NPHP4 | c.1535G>A p.R512Q | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs745851401, COSV65393423; called by muse, mutect2, varscan2
- NPNT | c.763+2T>A p.X255_splice | Splice Site (SNP) | VAF 13/166 reads (8%) | catalogued as COSV59755844; called by muse, mutect2
- NSD1 | c.3817C>T p.R1273C | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs779028625, COSV61776980; called by muse, mutect2, varscan2
- NSUN2 | c.1804C>T p.R602W | Missense Mutation (SNP) | VAF 71/184 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371887249; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NT5DC2 | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 41/170 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.21); catalogued as rs1294700491, COSV58737001; called by muse, mutect2, varscan2
- NTPCR | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as rs759051611, COSV64052222; called by muse, mutect2, varscan2
- NUMA1 | c.5428C>T p.R1810C | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779168913, COSV52621164; called by muse, mutect2
- NUP133 | c.412G>A p.V138I | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs368257231; called by muse, mutect2, varscan2
- NUP155 | c.1388C>T p.A463V (on ENST00000231498 / NM_153485.3; = p.A404V on NM_004298.4) | Missense Mutation (SNP) | VAF 82/177 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.096); catalogued as rs751958347, COSV51530379; called by muse, mutect2, varscan2
- NUP205 | c.5095G>T p.G1699W | Missense Mutation (SNP) | VAF 87/215 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as rs1373470406, COSV53659916; called by muse, mutect2, varscan2
- NUP50 | c.1186C>T p.R396W | Missense Mutation (SNP) | VAF 87/199 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61661079; called by muse, mutect2, varscan2
- NUTM1 | c.1037G>A p.R346Q | Missense Mutation (SNP) | VAF 60/146 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.127); catalogued as rs745953322, COSV59217101; called by muse, mutect2, varscan2
- NXF3 | c.197A>G p.Y66C | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.214); catalogued as COSV67703700; called by muse, mutect2, varscan2
- NYNRIN | c.1570G>A p.V524M | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.001); catalogued as rs373058068; called by muse, mutect2, varscan2
- OBSCN | c.6881G>A p.R2294H | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs556474884, COSV52760342; called by muse, mutect2, varscan2
- ODF1 | c.578G>A p.G193D | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.43); PolyPhen benign (0.322); catalogued as COSV53432710; called by muse, mutect2, varscan2
- OGFOD2 | c.250C>A p.L84I (on ENST00000228922 / NM_001304833.1; = p.L24I on NM_024623.3) | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV57441870; called by muse, mutect2, varscan2
- OPRM1 | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV57677767; called by muse, mutect2
- OR10G7 | c.107C>T p.T36I | Missense Mutation (SNP) | VAF 88/246 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.774); catalogued as COSV100389770; called by muse, mutect2
- OR10H5 | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 66/142 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.29); catalogued as rs763522556, COSV58277870; called by muse, mutect2, varscan2
- OR2C3 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as rs748026290, COSV63574391, COSV63575140; called by muse, mutect2, varscan2
- OR2M3 | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 131/324 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs748575324, COSV101513390, COSV71758967; called by muse, mutect2, varscan2
- OR4N2 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs770622276, COSV60050519; called by muse, mutect2, varscan2
- OR5M1 | c.325A>T p.I109F | Missense Mutation (SNP) | VAF 61/168 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.077); catalogued as rs1220622279, COSV73202161; called by muse, mutect2, varscan2
- OR6A2 | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs200095225; called by muse, mutect2, varscan2
1,018 further variants in this file (536 protein-altering or splice-affecting, 459 silent, 23 other) are not listed here.
